Somatic mutation profile of cancer-model specimen HCM-BROD-0099-C15-85A (3D Organoid, passage 8; aliquot HCM-BROD-0099-C15-85A-01D-A79C-36), derived from the primary tumor of HCMI case HCM-BROD-0099-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Age at diagnosis: 57.2 years (20,880 days).
Specimen HCM-BROD-0099-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df60865e-1a0a-4051-afa2-19405c483357.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0099-C15-10B (Blood Derived Normal), aliquot HCM-BROD-0099-C15-10B-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f5ae505c-0beb-4981-a939-a8d0a9043211

The open-access MAF lists 1,635 somatic variants for this specimen: 1,231 protein-altering or splice-affecting, 343 silent, 61 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 837, Silent 343, Frame Shift Del 193, Frame Shift Ins 141, Nonsense Mutation 27, Intron 26, In Frame Del 14, 3'UTR 13, 5'UTR 11, Splice Region 8, 5'Flank 7, Splice Site 5.

Variants (750 of 1,635; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP8B1 | c.614dup p.N205Kfs*2 | Frame Shift Ins (INS) | VAF 138/301 reads (46%) | catalogued as rs761784230; ClinVar: pathogenic; called by mutect2, varscan2
- BRCA2 | c.9097del p.T3033Lfs*29 | Frame Shift Del (DEL) | VAF 144/314 reads (46%) | catalogued as rs397507419; ClinVar: not provided / pathogenic; called by mutect2, varscan2
- CPLANE1 | c.*1148del | 3'UTR (DEL) | VAF 137/408 reads (34%) | catalogued as rs777686211; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- DLD | c.633dup p.V212Sfs*32 | Frame Shift Ins (INS) | VAF 96/202 reads (48%) | catalogued as rs1040811473; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 155/337 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GLB1 | c.1577del p.G526Afs*74 | Frame Shift Del (DEL) | VAF 292/695 reads (42%) | catalogued as rs794729217; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ITGB4 | c.600dup p.F201Lfs*15 | Frame Shift Ins (INS) | VAF 198/450 reads (44%) | catalogued as rs752657203; ClinVar: pathogenic; called by mutect2, varscan2
- NBN | c.1396dup p.R466Kfs*5 | Frame Shift Ins (INS) | VAF 128/319 reads (40%) | catalogued as rs1349928568; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- NKX6-2 | c.234del p.L79Cfs*109 | Frame Shift Del (DEL) | VAF 338/919 reads (37%) | catalogued as rs765650727; ClinVar: likely pathogenic; called by pindel, varscan2
- NRL | c.104dup p.T36Yfs*20 | Frame Shift Ins (INS) | VAF 359/930 reads (39%) | catalogued as rs1566561006; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RIN2 | c.1878dup p.I627Hfs*7 (on ENST00000255006 / NM_001242581.1; = p.I578Hfs*7 on NM_018993.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 160/360 reads (44%) | catalogued as rs759390822; ClinVar: pathogenic; called by mutect2, varscan2
- TALDO1 | c.512_514del p.S171del | In Frame Del (DEL) | VAF 192/197 reads (97%) | catalogued as rs137853085; ClinVar: pathogenic; called by pindel, varscan2
- TP53 | c.216del p.V73Wfs*50 | Frame Shift Del (DEL) | VAF 724/1010 reads (72%) | catalogued as rs730882018; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- AACS | c.1268A>G p.Y423C | Missense Mutation (SNP) | VAF 194/453 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751011092; called by muse, mutect2, varscan2
- ABCA10 | c.941dup p.I315Hfs*5 | Frame Shift Ins (INS) | VAF 149/359 reads (42%) | catalogued as rs771346448; called by mutect2, pindel, varscan2
- ABCA8 | c.2567C>A p.S856Y | Missense Mutation (SNP) | VAF 69/390 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV52198524, COSV52211859; called by muse, mutect2, varscan2
- ABCC12 | c.2317dup p.Q773Pfs*15 | Frame Shift Ins (INS) | VAF 214/408 reads (52%) | catalogued as rs868446631; called by mutect2, varscan2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 218/228 reads (96%) | catalogued as rs749943218; called by mutect2, varscan2
- ABR | c.2526dup p.I843Hfs*46 (on ENST00000302538 / NM_021962.5; = p.I806Hfs*46 on NM_001092.5) | Frame Shift Ins (INS) | VAF 236/510 reads (46%) | catalogued as rs750897785; called by mutect2, varscan2
- AC006059.2 | c.1109dup p.K371Efs*15 | Frame Shift Ins (INS) | VAF 228/532 reads (43%) | catalogued as rs1175736292; called by mutect2, pindel, varscan2
- AC009412.1 | c.83T>C p.L28P | Missense Mutation (SNP) | VAF 307/734 reads (42%) | SIFT deleterious (0); catalogued as COSV57626962; called by muse, varscan2
- ACP6 | c.1240G>A p.A414T | Missense Mutation (SNP) | VAF 195/405 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781901499, COSV65077762; called by muse, mutect2, varscan2
- ACTA1 | c.911del p.G304Afs*24 | Frame Shift Del (DEL) | VAF 99/709 reads (14%) | catalogued as CD142756, COSV64203291; called by mutect2, pindel, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 333/346 reads (96%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMTS18 | c.2085del p.F695Lfs*7 | Frame Shift Del (DEL) | VAF 157/338 reads (46%) | catalogued as rs772504358, COSV51414270; called by mutect2, varscan2
- ADAMTS8 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 451/834 reads (54%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs772968405; called by muse, mutect2, varscan2
- ADAMTSL4 | c.745dup p.L249Pfs*52 | Frame Shift Ins (INS) | VAF 206/558 reads (37%) | catalogued as rs761084716; called by mutect2, pindel, varscan2
- ADGB | c.3247C>T p.R1083C | Missense Mutation (SNP) | VAF 169/374 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1274771179; called by muse, mutect2, varscan2
- ADGRA1 | c.115C>G p.P39A | Missense Mutation (SNP) | VAF 416/750 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.218); catalogued as COSV101658597; called by muse, mutect2, varscan2
- ADGRA1 | c.1371dup p.S458Qfs*31 | Frame Shift Ins (INS) | VAF 452/936 reads (48%) | catalogued as rs1202605317; called by mutect2, varscan2
- ADRA2A | c.383A>G p.D128G | Missense Mutation (SNP) | VAF 436/849 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54529431; called by mutect2, varscan2
- AGO2 | c.1806del p.A603Pfs*92 | Frame Shift Del (DEL) | VAF 465/802 reads (58%) | catalogued as rs748399150; called by mutect2, varscan2
- AHCTF1 | c.1187G>A p.R396Q (on ENST00000366508; = p.R370Q on NM_015446.5) | Missense Mutation (SNP) | VAF 189/381 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as rs768685968; called by muse, mutect2, varscan2
- AHNAK | c.15185T>A p.V5062D | Missense Mutation (SNP) | VAF 354/681 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV57225331; called by muse, mutect2, varscan2
- AHNAK2 | c.8306C>T p.A2769V | Missense Mutation (SNP) | VAF 157/954 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs550119106, COSV100315464; called by muse, mutect2, varscan2
- AKAP17A | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 554/1142 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.404); catalogued as COSV58312219; called by muse, mutect2, varscan2
- AKAP17A | c.1216C>T p.R406W | Missense Mutation (SNP) | VAF 428/872 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1376345456; called by muse, varscan2
- AKAP6 | c.4613G>A p.R1538H | Missense Mutation (SNP) | VAF 91/549 reads (17%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs539925484, COSV55207514; called by muse, mutect2, varscan2
- ALDH16A1 | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 565/566 reads (100%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.448); catalogued as rs1015091964; called by muse, mutect2, varscan2
- ALPK1 | c.1924C>T p.H642Y | Missense Mutation (SNP) | VAF 34/405 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as rs532078134, COSV51585432, COSV51589555; called by muse, mutect2
- AMER2 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 415/791 reads (52%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs777199055; called by muse, mutect2, varscan2
- AMH | c.914dup p.A306Gfs*77 | Frame Shift Ins (INS) | VAF 386/1113 reads (35%) | catalogued as rs1377795855; called by pindel, varscan2
- ANKRD23 | c.500G>T p.G167V | Missense Mutation (SNP) | VAF 26/510 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1244839747; called by muse, mutect2
- ANKRD31 | c.4273dup p.I1425Nfs*9 | Frame Shift Ins (INS) | VAF 226/470 reads (48%) | catalogued as rs1233667551; called by mutect2, varscan2
- ANKS1B | c.2884A>G p.R962G (on ENST00000547776 / NM_152788.4; = p.R188G on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 154/349 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs993414900, COSV59124016; called by muse, mutect2, varscan2
- AP5S1 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 192/397 reads (48%) | SIFT tolerated (0.6); PolyPhen benign (0.013); catalogued as rs777244137, COSV55694279; called by muse, mutect2, varscan2
- AP5Z1 | c.2086del p.Q696Rfs*6 | Frame Shift Del (DEL) | VAF 290/664 reads (44%) | catalogued as rs771683676, COSV100804281; called by mutect2, varscan2
- APOBEC2 | c.246A>C p.Q82H | Missense Mutation (SNP) | VAF 59/774 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as COSV55143728; called by muse, mutect2
- ARAP1 | c.3905G>A p.R1302H (on ENST00000393609 / NM_001040118.2; = p.R1057H on NM_015242.4) | Missense Mutation (SNP) | VAF 303/587 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754149945, COSV61993674; called by muse, mutect2, varscan2
- ARAP2 | c.4336_4338del p.E1446del | In Frame Del (DEL) | VAF 98/240 reads (41%) | catalogued as rs775660152; called by pindel, varscan2
- ARHGAP18 | c.488del p.N163Tfs*55 | Frame Shift Del (DEL) | VAF 186/413 reads (45%) | catalogued as rs749346165; called by mutect2, varscan2
- ARHGAP20 | c.3367A>G p.S1123G | Missense Mutation (SNP) | VAF 27/501 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV52806782; called by muse, mutect2
- ASMTL | c.1709T>C p.L570P | Missense Mutation (SNP) | VAF 53/978 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.908); catalogued as rs768381423; called by muse, mutect2
- ATF5 | c.109del p.L37Wfs*31 | Frame Shift Del (DEL) | VAF 930/1306 reads (71%) | catalogued as rs768611141; called by mutect2, pindel, varscan2
- ATP8B3 | c.1804G>A p.A602T | Missense Mutation (SNP) | VAF 64/627 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754467645; called by muse, varscan2
- ATP8B4 | c.1378G>T p.G460C | Missense Mutation (SNP) | VAF 215/215 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755705346; called by muse, mutect2, varscan2
- BABAM2 | c.488dup p.N163Kfs*6 | Frame Shift Ins (INS) | VAF 106/234 reads (45%) | catalogued as rs373964958; called by mutect2, varscan2
- BCL9L | c.3331G>A p.A1111T | Missense Mutation (SNP) | VAF 496/972 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52685927; called by muse, mutect2, varscan2
- BCOR | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 286/286 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.858); catalogued as rs778129253, COSV60719250; called by muse, mutect2, varscan2
- BEND4 | c.1181A>G p.Y394C | Missense Mutation (SNP) | VAF 243/464 reads (52%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.936); catalogued as rs538291585; called by muse, mutect2, varscan2
- BICC1 | c.998A>G p.Y333C | Missense Mutation (SNP) | VAF 219/498 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs1249340038; called by muse, mutect2, varscan2
- BLNK | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 344/702 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV99814109; called by muse, mutect2, varscan2
- BPTF | c.3026A>C p.K1009T | Missense Mutation (SNP) | VAF 34/301 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58831150; called by muse, mutect2, varscan2
- BRWD1 | c.5446dup p.T1816Nfs*6 | Frame Shift Ins (INS) | VAF 194/404 reads (48%) | catalogued as rs1568856013; called by mutect2, varscan2
- BSN | c.1945G>A p.V649I | Missense Mutation (SNP) | VAF 67/488 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs779715067, COSV56521334; called by muse, mutect2, varscan2
- BTN3A2 | c.949del p.I317Sfs*4 | Frame Shift Del (DEL) | VAF 232/566 reads (41%) | catalogued as COSV62687981; called by mutect2, pindel, varscan2
- C21orf91 | c.799G>A p.V267I (on ENST00000284881 / NM_001100420.2; = p.V266I on NM_017447.4) | Missense Mutation (SNP) | VAF 178/406 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs752922725, COSV53033144; called by muse, varscan2
- C3orf85 | c.118A>G p.N40D | Missense Mutation (SNP) | VAF 42/488 reads (9%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.065); catalogued as COSV101516311; called by muse, mutect2
- C4orf54 | c.1609C>T p.R537C | Missense Mutation (SNP) | VAF 327/561 reads (58%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs866088896; called by muse, mutect2, varscan2
- C5orf38 | c.226del p.D76Mfs*5 | Frame Shift Del (DEL) | VAF 226/775 reads (29%) | catalogued as rs746245907, COSV57410849; called by mutect2, pindel, varscan2
- CACNA1B | c.133T>C p.Y45H | Missense Mutation (SNP) | VAF 96/990 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as rs1220879681; called by muse, mutect2
- CACNA1F | c.3814A>G p.T1272A | Missense Mutation (SNP) | VAF 304/304 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.653); catalogued as rs1557106783; called by muse, mutect2, varscan2
- CACNA1G | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 236/464 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1478327583, COSV100661242; called by muse, mutect2, varscan2
- CACNA1H | c.3581G>A p.R1194Q | Missense Mutation (SNP) | VAF 425/1105 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs759668583; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1H | c.5209G>A p.A1737T | Missense Mutation (SNP) | VAF 356/687 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs61372944, COSV100673569; called by muse, mutect2, varscan2
- CAMTA1 | c.303A>G p.R101= | Splice Region (SNP) | VAF 150/288 reads (52%) | catalogued as rs1235140468; called by muse, mutect2, varscan2
- CAPG | c.670C>A p.L224M | Missense Mutation (SNP) | VAF 198/388 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as COSV99809370; called by muse, mutect2, varscan2
- CARD14 | c.2921G>A p.G974D | Missense Mutation (SNP) | VAF 422/902 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100413504; called by muse, mutect2, varscan2
- CBX2 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 364/754 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.333); catalogued as rs1351261350; called by muse, mutect2, varscan2
- CCDC137 | c.495del p.A166Rfs*7 | Frame Shift Del (DEL) | VAF 157/371 reads (42%) | catalogued as rs1435124182; called by mutect2, pindel, varscan2
- CCDC178 | c.874del p.M292Wfs*3 | Frame Shift Del (DEL) | VAF 116/222 reads (52%) | catalogued as rs535192849; called by mutect2, varscan2
- CCR6 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 249/577 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.166); catalogued as rs201556077, COSV100551020, COSV59474209, COSV59475783; called by muse, mutect2, varscan2
- CD5L | c.677A>C p.N226T | Missense Mutation (SNP) | VAF 29/393 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.175); catalogued as COSV100941226; called by muse, mutect2
- CDC37 | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 125/803 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs755464378, COSV55769371; called by muse, mutect2, varscan2
- CDKL1 | c.22del p.I8Lfs*38 | Frame Shift Del (DEL) | VAF 157/416 reads (38%) | catalogued as rs1566616984; called by mutect2, pindel, varscan2
- CDON | c.2177G>A p.R726Q | Missense Mutation (SNP) | VAF 119/312 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761883698, COSV99700812; called by muse, mutect2, varscan2
- CDYL | c.1702G>A p.E568K (on ENST00000328908 / NM_001368125.1; = p.E514K on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 241/469 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.415); catalogued as rs748790925; called by muse, mutect2, varscan2
- CEBPZ | c.2626G>A p.G876R | Missense Mutation (SNP) | VAF 16/402 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as rs1249092752; called by muse, mutect2
- CELSR3 | c.7714C>T p.R2572C | Missense Mutation (SNP) | VAF 390/844 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs759393208, COSV50842866; called by muse, mutect2, varscan2
- CENPC | c.616del p.R206Gfs*2 | Frame Shift Del (DEL) | VAF 87/194 reads (45%) | catalogued as rs1325731082; called by mutect2, pindel, varscan2
- CLCN1 | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 232/483 reads (48%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs201327261; called by muse, mutect2, varscan2
- CLK3 | c.1225C>T p.R409W (on ENST00000395066 / NM_001130028.1; = p.R261W on NM_003992.4) | Missense Mutation (SNP) | VAF 236/472 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.748); catalogued as rs1159353958; called by muse, mutect2
- CLSPN | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 209/470 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs760376374; called by muse, mutect2, varscan2
- CNTLN | c.1234C>A p.L412I | Missense Mutation (SNP) | VAF 144/326 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.586); catalogued as COSV52087517; called by muse, varscan2
- COL5A1 | c.1964G>A p.G655E | Missense Mutation (SNP) | VAF 40/570 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65666318; called by muse, mutect2
- COLEC12 | c.1968del p.K656Nfs*4 | Frame Shift Del (DEL) | VAF 156/409 reads (38%) | catalogued as COSV101232229; called by mutect2, pindel, varscan2
- COX7A2 | c.53T>C p.L18S | Missense Mutation (SNP) | VAF 188/376 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as rs1287771274; called by muse, mutect2, varscan2
- CPLX2 | c.13A>G p.M5V | Missense Mutation (SNP) | VAF 440/450 reads (98%) | SIFT tolerated (0.18); PolyPhen benign (0.072); catalogued as rs1217258172, COSV63999590; called by muse, mutect2, varscan2
- CRYBG1 | c.620del p.P207Lfs*29 | Frame Shift Del (DEL) | VAF 431/1059 reads (41%) | catalogued as rs1018039182; called by mutect2, pindel, varscan2
- CSMD3 | c.10460A>G p.K3487R (on ENST00000297405 / NM_001363185.1; = p.K3318R on NM_052900.3) | Missense Mutation (SNP) | VAF 165/430 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as COSV52183546; called by muse, varscan2
- CTC1 | c.3367G>A p.G1123R | Missense Mutation (SNP) | VAF 200/415 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs1336846960; called by muse, mutect2, varscan2
- CTSK | c.158del p.N53Tfs*2 | Frame Shift Del (DEL) | VAF 186/438 reads (42%) | catalogued as rs764168526; called by mutect2, pindel, varscan2
- CWC15 | c.407T>A p.I136N | Missense Mutation (SNP) | VAF 175/360 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1355194236, COSV99688675; called by muse, mutect2, varscan2
- CYP1A2 | c.398G>A p.W133* | Nonsense Mutation (SNP) | VAF 260/618 reads (42%) | catalogued as rs1476915394; called by muse, mutect2, varscan2
- CYSLTR2 | c.356A>G p.Y119C | Missense Mutation (SNP) | VAF 227/480 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375669186; called by muse, mutect2, varscan2
- DAB1 | c.885del p.T296Lfs*70 (on ENST00000371231; = p.T263Lfs*70 on NM_021080.5 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 174/415 reads (42%) | catalogued as COSV104428367; called by mutect2, pindel, varscan2
- DCAF12L1 | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 441/441 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1284451282, COSV64422872; called by muse, mutect2, varscan2
- DCDC2C | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 530/1025 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs960748580; called by muse, mutect2, varscan2
- DCHS1 | c.2641C>T p.R881C | Missense Mutation (SNP) | VAF 343/349 reads (98%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs760313532; called by muse, mutect2, varscan2
- DDHD1 | c.990A>C p.K330N (on ENST00000323669; = p.K527N on NM_030637.3) | Missense Mutation (SNP) | VAF 237/487 reads (49%) | SIFT tolerated (0.58); PolyPhen benign (0.014); catalogued as COSV60362049; called by muse, mutect2, varscan2
- DGKE | c.1694C>T p.A565V | Missense Mutation (SNP) | VAF 113/266 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); catalogued as rs547304654; called by muse, mutect2, varscan2
- DIPK1B | c.673T>C p.C225R | Missense Mutation (SNP) | VAF 453/928 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs964835698; called by muse, mutect2, varscan2
- DLGAP4 | c.2825G>A p.R942H (on ENST00000339266 / NM_001365621.1; = p.R939H on NM_014902.6) | Missense Mutation (SNP) | VAF 554/815 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757785334, COSV59414319; called by muse, mutect2, varscan2
- DMRTA2 | c.1400G>T p.R467L | Missense Mutation (SNP) | VAF 54/916 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs781478910; called by muse, mutect2
- DOCK9 | c.2579G>T p.G860V (on ENST00000376460 / NM_001366676.2; = p.G861V on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/378 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.022); catalogued as rs781212295; called by muse, mutect2, varscan2
- DPH5 | c.623_625del p.G208del | In Frame Del (DEL) | VAF 98/226 reads (43%) | catalogued as rs779889468; called by pindel, varscan2
- DPP6 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 68/118 reads (58%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.003); catalogued as rs1263209878; called by muse, varscan2
- DRC1 | c.1851del p.W618Gfs*19 | Frame Shift Del (DEL) | VAF 203/522 reads (39%) | catalogued as rs781097632, COSV55514089; called by mutect2, pindel, varscan2
- DSCAM | c.5628del p.K1877Nfs*8 | Frame Shift Del (DEL) | VAF 212/512 reads (41%) | catalogued as rs766229789; called by mutect2, pindel, varscan2
- DTX2 | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 172/740 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.079); catalogued as rs764883046, COSV56859892; called by muse, mutect2, varscan2
- DYNC1H1 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 128/258 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.66); catalogued as rs201746558, COSV64134550; called by muse, mutect2, varscan2
- DZIP1 | c.497A>G p.Q166R | Missense Mutation (SNP) | VAF 289/558 reads (52%) | SIFT tolerated (0.46); PolyPhen benign (0.196); catalogued as rs756850664; called by muse, mutect2, varscan2
- EFCAB5 | c.437dup p.A147Gfs*2 | Frame Shift Ins (INS) | VAF 178/352 reads (51%) | catalogued as rs767553068; called by mutect2, varscan2
- EHBP1 | c.2018C>G p.S673C | Missense Mutation (SNP) | VAF 224/471 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.285); catalogued as COSV50431558; called by muse, varscan2
- EIF2AK1 | c.592del p.I198Sfs*2 | Frame Shift Del (DEL) | VAF 106/232 reads (46%) | catalogued as rs767715156, COSV104389006; called by mutect2, varscan2
- EIF5 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 156/380 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV53684838, COSV53685476; called by muse, mutect2, varscan2
- EPHA10 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 23/832 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60403672; called by muse, mutect2
- EPHA3 | c.1925T>C p.L642P | Missense Mutation (SNP) | VAF 171/360 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV60700624; called by muse, mutect2, varscan2
- EPHX1 | c.1082A>G p.Y361C | Missense Mutation (SNP) | VAF 211/405 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771190130; called by muse, mutect2, varscan2
- ERMP1 | c.1951del p.T651Pfs*3 | Frame Shift Del (DEL) | VAF 152/418 reads (36%) | catalogued as rs753821453; called by mutect2, varscan2
- ESF1 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 219/534 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1277847783, COSV52520081; called by muse, mutect2, varscan2
- ESPNL | c.719C>G p.A240G | Missense Mutation (SNP) | VAF 761/774 reads (98%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV58037116; called by muse, mutect2, varscan2
- FAM135A | c.2996del p.N999Ifs*5 (on ENST00000370479 / NM_001351599.1; = p.N786Ifs*5 on NM_020819.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 137/276 reads (50%) | catalogued as rs780725577; called by mutect2, varscan2
- FAM186B | c.1546_1548del p.E516del | In Frame Del (DEL) | VAF 342/755 reads (45%) | catalogued as rs1445707432; called by mutect2, pindel, varscan2
- FAM20A | c.129del p.C44Afs*101 | Frame Shift Del (DEL) | VAF 432/1058 reads (41%) | catalogued as rs1567756818; called by mutect2, pindel, varscan2
- FAM214B | c.124del p.A42Rfs*25 | Frame Shift Del (DEL) | VAF 366/913 reads (40%) | catalogued as rs746881923; called by mutect2, pindel, varscan2
- FAM83H | c.1639C>T p.R547C | Missense Mutation (SNP) | VAF 98/2448 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as rs782349627; called by muse, mutect2
- FAM91A1 | c.1958G>A p.C653Y | Missense Mutation (SNP) | VAF 349/578 reads (60%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV58238025; called by muse, varscan2
- FANCE | c.544del p.Q182Rfs*114 | Frame Shift Del (DEL) | VAF 229/608 reads (38%) | catalogued as rs1561789651, COSV100003664; called by mutect2, pindel, varscan2
- FANCI | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 195/449 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as CM074783; called by muse, mutect2, varscan2
- FAR2 | c.1329del p.K443Nfs*4 | Frame Shift Del (DEL) | VAF 154/378 reads (41%) | catalogued as COSV99479542; called by mutect2, pindel, varscan2
- FBXL19 | c.1315C>T p.R439W | Missense Mutation (SNP) | VAF 369/778 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1399898651; called by muse, mutect2, varscan2
- FCRL3 | c.814del p.R272Gfs*3 | Frame Shift Del (DEL) | VAF 161/352 reads (46%) | catalogued as rs1288807478; called by mutect2, pindel, varscan2
- FER1L5 | c.3259C>T p.P1087S (on ENST00000623019; = p.P1060S on NM_001293083.2) | Missense Mutation (SNP) | VAF 266/559 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.04); catalogued as rs1305696916; called by muse, varscan2
- FERMT1 | c.1616C>T p.A539V | Missense Mutation (SNP) | VAF 235/528 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs770476471; called by muse, mutect2
- FGR | c.638G>T p.R213L | Missense Mutation (SNP) | VAF 274/592 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV100925930; called by muse, mutect2, varscan2
- FLG | c.448A>G p.K150E | Missense Mutation (SNP) | VAF 236/516 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); catalogued as rs756351291, COSV64235927; called by mutect2, varscan2
- FLYWCH1 | c.742del p.R248Efs*6 (on ENST00000253928 / NM_001308068.2; = p.R247Efs*6 on NM_020912.1 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 359/811 reads (44%) | catalogued as COSV54147393; called by mutect2, pindel, varscan2
- FMN2 | c.4402C>T p.R1468C | Missense Mutation (SNP) | VAF 162/353 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as rs748812254, COSV100144530, COSV60425638; called by muse, mutect2, varscan2
- FNDC5 | c.618del p.L207Ffs*69 | Frame Shift Del (DEL) | VAF 318/803 reads (40%) | catalogued as COSV65106005; called by mutect2, pindel, varscan2
- FOSB | c.822del p.N275Tfs*2 | Frame Shift Del (DEL) | VAF 414/1065 reads (39%) | catalogued as COSV62279449; called by mutect2, pindel, varscan2
- FOXF1 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 407/893 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1293500536, COSV52285464; called by muse, mutect2, varscan2
- FOXG1 | c.571A>T p.M191L | Missense Mutation (SNP) | VAF 63/822 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100487084; called by muse, mutect2
- FOXI1 | c.78dup p.E27Rfs*7 | Frame Shift Ins (INS) | VAF 318/541 reads (59%) | catalogued as rs776996183; called by pindel, varscan2
- FRMD4A | c.3014dup p.S1006Kfs*25 | Frame Shift Ins (INS) | VAF 236/258 reads (91%) | catalogued as rs752538869; called by mutect2, varscan2
- FSIP2 | c.8038del p.T2680Hfs*3 | Frame Shift Del (DEL) | VAF 390/413 reads (94%) | catalogued as rs755234663; called by mutect2, varscan2
- GBP7 | c.1293dup p.H432Afs*12 | Frame Shift Ins (INS) | VAF 210/464 reads (45%) | catalogued as rs754177800; called by mutect2, varscan2
- GFM1 | c.843A>G p.L281= | Splice Region (SNP) | VAF 168/341 reads (49%) | catalogued as rs759440642; ClinVar: likely benign; called by muse, mutect2, varscan2
- GFRA4 | c.173G>A p.G58D | Missense Mutation (SNP) | VAF 435/796 reads (55%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs1487861516; called by muse, mutect2, varscan2
- GJA8 | c.263del p.P88Rfs*3 | Frame Shift Del (DEL) | VAF 276/707 reads (39%) | catalogued as COSV53789902; called by mutect2, pindel, varscan2
- GLG1 | c.3331C>T p.R1111C | Missense Mutation (SNP) | VAF 176/394 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs1244624471; called by muse, mutect2, varscan2
- GLI2 | c.3119A>G p.E1040G (on ENST00000361492 / NM_001374353.1; = p.E1057G on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 526/1059 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV58044171; called by muse, mutect2, varscan2
- GLI3 | c.3031A>G p.T1011A | Missense Mutation (SNP) | VAF 28/1210 reads (2%) | SIFT tolerated (0.44); PolyPhen benign (0.044); catalogued as rs1397866934; called by muse, mutect2
- GPR151 | c.110C>T p.T37I | Missense Mutation (SNP) | VAF 18/550 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as rs1380712496; called by muse, mutect2
- GPRASP1 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 364/364 reads (100%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs781232292, COSV100851060; called by muse, mutect2, varscan2
- GRAMD2B | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 18/396 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1052869985; called by muse, mutect2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 204/222 reads (92%) | catalogued as rs760757380; called by mutect2, varscan2
- GRSF1 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 36/1302 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs1194430876; called by muse, mutect2
- GRXCR2 | c.239T>C p.L80P | Missense Mutation (SNP) | VAF 262/582 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1244490927; called by muse, mutect2, varscan2
- GTF2F2 | c.275C>T p.T92I | Missense Mutation (SNP) | VAF 162/341 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.056); catalogued as rs746742188; called by muse, mutect2, varscan2
- GTF2IRD2B | c.2479G>A p.A827T | Missense Mutation (SNP) | VAF 259/755 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as rs1554454661; called by muse, mutect2, varscan2
- GUF1 | c.1934del p.K645Sfs*2 | Frame Shift Del (DEL) | VAF 131/276 reads (47%) | catalogued as COSV54945907; called by mutect2, varscan2
- HADHA | c.2219A>G p.Y740C | Missense Mutation (SNP) | VAF 281/616 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66108303; called by muse, mutect2, varscan2
- HECTD3 | c.88C>T p.L30F | Missense Mutation (SNP) | VAF 24/946 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55800580; called by muse, mutect2
- HIF1A | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 135/298 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as rs755629700, COSV60192627; called by muse, mutect2, varscan2
- HK1 | c.1321C>T p.R441C | Missense Mutation (SNP) | VAF 287/588 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as rs148472311; called by muse, mutect2, varscan2
- HM13 | c.126G>A p.M42I | Missense Mutation (SNP) | VAF 480/1487 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1300852357; called by muse, mutect2, varscan2
- HMX2 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 137/737 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60593937; called by muse, mutect2, varscan2
- HOXA3 | c.1324C>T p.H442Y | Missense Mutation (SNP) | VAF 249/522 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs746664809; called by muse, varscan2
- HPX | c.951del p.K317Nfs*14 | Frame Shift Del (DEL) | VAF 32/224 reads (14%) | catalogued as COSV56418544; called by mutect2, pindel, varscan2
- HTATSF1 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 236/238 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV54479699; called by muse, varscan2
- IDE | c.2020C>T p.R674W | Missense Mutation (SNP) | VAF 163/302 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs1394653409; called by muse, varscan2
- IFFO1 | c.1089del p.R364Gfs*47 (on ENST00000396840 / NM_001330324.2; = p.R367Gfs*47 on NM_080730.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 278/294 reads (95%) | catalogued as rs750779916, COSV60737300; called by mutect2, varscan2
- IFIH1 | c.2650A>G p.K884E | Missense Mutation (SNP) | VAF 35/367 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV99718950; called by muse, mutect2
- IFRD1 | c.916dup p.Y306Lfs*2 | Frame Shift Ins (INS) | VAF 96/194 reads (49%) | catalogued as rs979653918; called by mutect2, varscan2
- IFT46 | c.898A>G p.T300A (on ENST00000264021 / NM_001168618.2; = p.T351A on NM_020153.3) | Missense Mutation (SNP) | VAF 168/370 reads (45%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.018); catalogued as rs782548690; called by muse, mutect2, varscan2
- IGFBP4 | c.740T>C p.L247P | Missense Mutation (SNP) | VAF 320/672 reads (48%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.992); catalogued as COSV54098643; called by muse, mutect2, varscan2
- IGFBPL1 | c.56T>C p.L19P | Missense Mutation (SNP) | VAF 326/649 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.902); catalogued as rs1419174396; called by muse, varscan2
- IGHV1-2 | c.245A>C p.K82T | Missense Mutation (SNP) | VAF 212/439 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.102); catalogued as rs557034159; called by muse, mutect2, varscan2
- IGHV3-15 | c.159G>A p.M53I | Missense Mutation (SNP) | VAF 48/463 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.866); catalogued as rs1555443711; called by muse, mutect2, varscan2
- IGLV3-27 | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 209/440 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1437035494; called by muse, mutect2, varscan2
- IGSF3 | c.1978C>T p.R660* (on ENST00000369486 / NM_001007237.3; = p.R680* on NM_001542.4) | Nonsense Mutation (SNP) | VAF 281/705 reads (40%) | catalogued as COSV59595185; called by muse, mutect2, varscan2
- IL6R | c.499T>C p.Y167H | Missense Mutation (SNP) | VAF 231/465 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1468329259; called by muse, mutect2, varscan2
- INKA2 | c.825del p.T276Qfs*25 | Frame Shift Del (DEL) | VAF 68/555 reads (12%) | catalogued as rs759002690; called by mutect2, pindel, varscan2
- IRS2 | c.3376C>T p.P1126S | Missense Mutation (SNP) | VAF 538/1122 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.275); catalogued as rs545026034; called by muse, mutect2, varscan2
- IRX4 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 47/1471 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV51475035, COSV99181922; called by muse, mutect2
- ISLR | c.1280C>A p.S427Y | Missense Mutation (SNP) | VAF 66/639 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); catalogued as COSV51435708; called by muse, mutect2
- JMJD1C | c.6075dup p.E2026Rfs*8 | Frame Shift Ins (INS) | VAF 152/288 reads (53%) | catalogued as rs1226801045; called by mutect2, varscan2
- KCNB2 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 772/1058 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73049052; called by muse, mutect2, varscan2
- KCNQ3 | c.556G>T p.G186C | Missense Mutation (SNP) | VAF 467/749 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66470464; called by muse, mutect2, varscan2
- KCNS3 | c.1028A>G p.Y343C | Missense Mutation (SNP) | VAF 311/625 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs140699625; called by muse, mutect2, varscan2
- KDM2B | c.77dup p.K27Efs*10 | Frame Shift Ins (INS) | VAF 196/412 reads (48%) | catalogued as rs782541016; called by mutect2, varscan2
- KDM3A | c.974C>T p.S325F | Missense Mutation (SNP) | VAF 35/299 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs200618359, COSV57217731; called by muse, mutect2, varscan2
- KIAA0513 | c.1222A>G p.M408V | Missense Mutation (SNP) | VAF 239/480 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.914); catalogued as rs888927602, COSV99260898; called by muse, mutect2, varscan2
- KIAA2013 | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 298/663 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as rs145156794; called by muse, mutect2, varscan2
- KIF6 | c.611del p.L204* | Frame Shift Del (DEL) | VAF 116/307 reads (38%) | catalogued as rs777890702; called by mutect2, pindel, varscan2
- KIT | c.1729C>A p.P577T | Missense Mutation (SNP) | VAF 58/397 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55386835; called by muse, mutect2, varscan2
- KLHL36 | c.1592C>T p.P531L | Missense Mutation (SNP) | VAF 426/830 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs754689351; called by muse, mutect2
- KMT2C | c.1039T>C p.C347R | Missense Mutation (SNP) | VAF 99/801 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51383526; called by muse, varscan2
- KRT75 | c.1346C>T p.A449V | Missense Mutation (SNP) | VAF 21/537 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52875262; called by muse, mutect2
- KRTAP10-8 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 190/389 reads (49%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs991800614, COSV58166303; called by muse, mutect2, varscan2
- KRTAP29-1 | c.905G>A p.G302D | Missense Mutation (SNP) | VAF 509/1005 reads (51%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.96); catalogued as COSV66939773; called by muse, mutect2, varscan2
- L1TD1 | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 165/353 reads (47%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs375545502; called by muse, mutect2, varscan2
- LAMB2 | c.2524C>A p.L842I | Missense Mutation (SNP) | VAF 127/572 reads (22%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.446); catalogued as rs1380503405; called by muse, mutect2, varscan2
- LANCL2 | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 221/451 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV54652115; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 165/227 reads (73%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LDHD | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 312/651 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1233919146, COSV55581830; called by muse, mutect2, varscan2
- LMTK2 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 198/421 reads (47%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.564); catalogued as rs747890701, COSV99807036; called by muse, mutect2
- LMX1B | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 27/605 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as CM992924, COSV100827317; called by muse, mutect2
- LRFN2 | c.479A>C p.N160T | Missense Mutation (SNP) | VAF 316/649 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs76425995; called by muse, mutect2, varscan2
- LRP12 | c.1351dup p.C451Lfs*9 | Frame Shift Ins (INS) | VAF 224/729 reads (31%) | catalogued as rs35928649; called by mutect2, varscan2
- LRRC42 | c.1187T>C p.F396S | Missense Mutation (SNP) | VAF 229/463 reads (49%) | SIFT tolerated (0.5); PolyPhen benign (0.018); catalogued as COSV59961776; called by muse, mutect2, varscan2
- LRRC8C | c.1540C>T p.R514* | Nonsense Mutation (SNP) | VAF 150/322 reads (47%) | catalogued as rs746628711, COSV64996251; called by muse, mutect2, varscan2
- LRRCC1 | c.2320G>A p.A774T | Missense Mutation (SNP) | VAF 198/346 reads (57%) | SIFT deleterious (0.05); PolyPhen benign (0.248); catalogued as COSV99066558; called by muse, mutect2, varscan2
- LRRIQ1 | c.1544C>G p.S515C | Missense Mutation (SNP) | VAF 64/284 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as COSV67828792; called by muse, varscan2
- LRRK2 | c.2756A>G p.D919G | Missense Mutation (SNP) | VAF 102/250 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.046); catalogued as rs1312779682; called by muse, mutect2, varscan2
- LRRTM1 | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 390/788 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs528982180; called by muse, mutect2, varscan2
- LRRTM1 | c.816G>T p.E272D | Missense Mutation (SNP) | VAF 305/643 reads (47%) | SIFT tolerated (0.96); PolyPhen benign (0.085); catalogued as COSV99701961; called by muse, mutect2, varscan2
- LTBP3 | c.3910T>C p.*1304Rext*12 (on ENST00000301873 / NM_001130144.3; = p.*1257Rext*12 on NM_021070.4 and 1 other RefSeq transcript) | Nonstop Mutation (SNP) | VAF 332/685 reads (48%) | catalogued as rs1259084776; called by muse, mutect2, varscan2
- MACF1 | c.4084G>A p.E1362K | Missense Mutation (SNP) | VAF 20/470 reads (4%) | catalogued as rs1204948099; called by muse, mutect2
- MAP3K4 | c.4635G>A p.W1545* | Nonsense Mutation (SNP) | VAF 131/309 reads (42%) | catalogued as COSV62336676; called by muse, mutect2, varscan2
- MAPK8IP2 | c.1592G>T p.G531V | Missense Mutation (SNP) | VAF 430/924 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV50498539; called by muse, mutect2
- MAST3 | c.1652T>C p.V551A | Missense Mutation (SNP) | VAF 267/555 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53221464; called by muse, mutect2, varscan2
- MBD6 | c.2080dup p.Q694Pfs*23 | Frame Shift Ins (INS) | VAF 47/124 reads (38%) | catalogued as rs762648935; called by mutect2, varscan2
- MDM2 | c.961del p.L321Ffs*52 | Frame Shift Del (DEL) | VAF 164/439 reads (37%) | catalogued as rs746910913; called by mutect2, pindel, varscan2
- MEF2A | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 50/234 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as rs1206225537; called by muse, mutect2, varscan2
- MEOX2 | c.496A>G p.K166E | Missense Mutation (SNP) | VAF 250/544 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); catalogued as rs1297638941; called by muse, mutect2, varscan2
- METTL14 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 161/278 reads (58%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.993); catalogued as COSV66311386; called by muse, mutect2, varscan2
- MICALL2 | c.1211dup p.A405Sfs*15 | Frame Shift Ins (INS) | VAF 303/674 reads (45%) | catalogued as rs767131208; called by mutect2, varscan2
- MIER3 | c.1027del p.R343Dfs*15 (on ENST00000381199 / NM_001297599.2; = p.R342Dfs*15 on NM_152622.4) | Frame Shift Del (DEL) | VAF 151/294 reads (51%) | catalogued as COSV67083276; called by mutect2, varscan2
- MMP25 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 318/647 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV100339469; called by muse, varscan2
- MMRN2 | c.2284A>G p.M762V | Missense Mutation (SNP) | VAF 339/669 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1298885800; called by muse, mutect2, varscan2
- MORC4 | c.1del p.M1? | Frame Shift Del (DEL) | VAF 136/193 reads (70%) | catalogued as rs759643903; called by mutect2, pindel, varscan2
- MRE11 | c.1532del p.N511Ifs*13 | Frame Shift Del (DEL) | VAF 145/389 reads (37%) | catalogued as rs757691558; called by mutect2, pindel, varscan2
- MROH2B | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 30/390 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV68183058; called by muse, mutect2
- MRPL4 | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 262/557 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1215912278, COSV53449697; called by muse, mutect2, varscan2
- MS4A15 | c.475A>G p.M159V (on ENST00000405633 / NM_001098835.2; = p.M66V on NM_152717.3) | Missense Mutation (SNP) | VAF 198/393 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.127); catalogued as rs1178482302; called by muse, mutect2, varscan2
- MSANTD1 | c.41T>G p.L14R | Missense Mutation (SNP) | VAF 421/830 reads (51%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.191); catalogued as rs921891304; called by muse, mutect2, varscan2
- MTMR12 | c.1925G>A p.R642H | Missense Mutation (SNP) | VAF 265/881 reads (30%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.999); catalogued as rs754133953, COSV53784261; called by muse, mutect2, varscan2
- MUC16 | c.9283A>C p.T3095P | Missense Mutation (SNP) | VAF 42/612 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.383); catalogued as COSV67499963; called by muse, mutect2
- MUL1 | c.1025C>T p.A342V | Missense Mutation (SNP) | VAF 202/421 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.025); catalogued as rs558469333, COSV51642966; called by muse, mutect2, varscan2
- MUTYH | c.498G>A p.E166= | Splice Region (SNP) | VAF 203/499 reads (41%) | catalogued as rs764546111; ClinVar: likely benign; called by muse, mutect2
- MYO9B | c.5023C>T p.H1675Y | Missense Mutation (SNP) | VAF 20/582 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV68281306; called by muse, mutect2
- MYPN | c.2464C>T p.R822W | Missense Mutation (SNP) | VAF 326/637 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs529221329, COSV100589576; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYPN | c.3272G>A p.R1091Q | Missense Mutation (SNP) | VAF 39/242 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.653); catalogued as rs768452699; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NALCN | c.2362G>T p.D788Y | Missense Mutation (SNP) | VAF 146/307 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as COSV51964021; called by muse, mutect2, varscan2
- NAPRT | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 1067/2022 reads (53%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs774761219, COSV52782619; called by muse, mutect2, varscan2
- NAV1 | c.1544G>A p.G515E | Missense Mutation (SNP) | VAF 275/606 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.771); catalogued as rs766634119, COSV55228191; called by muse, mutect2, varscan2
- NBEAL2 | c.7253G>T p.G2418V | Missense Mutation (SNP) | VAF 83/653 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99434339; called by muse, mutect2, varscan2
- NCAPG | c.1817del p.L606Yfs*32 | Frame Shift Del (DEL) | VAF 39/300 reads (13%) | catalogued as COSV52270010; called by mutect2, pindel, varscan2
- NEB | c.2783del p.P928Lfs*29 | Frame Shift Del (DEL) | VAF 428/599 reads (71%) | catalogued as rs751346602; called by mutect2, pindel, varscan2
- NEK5 | c.409A>C p.S137R | Missense Mutation (SNP) | VAF 17/381 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62882325; called by muse, mutect2
- NELFCD | c.287A>G p.Y96C (on ENST00000602795; = p.Y78C on NM_198976.4) | Missense Mutation (SNP) | VAF 188/654 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753983399; called by muse, mutect2, varscan2
- NFIC | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 38/951 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.278); catalogued as rs1175118397; called by muse, mutect2
- NFKBIZ | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 27/559 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); catalogued as COSV58200938; called by muse, mutect2
- NLE1 | c.635C>T p.A212V | Missense Mutation (SNP) | VAF 209/403 reads (52%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs144949018; called by muse, mutect2, varscan2
- NLRP7 | c.1231G>A p.A411T | Missense Mutation (SNP) | VAF 1134/1162 reads (98%) | SIFT tolerated (0.35); PolyPhen benign (0.022); catalogued as rs746988595, COSV60175739; called by muse, mutect2, varscan2
- NOTCH1 | c.5282G>A p.R1761Q | Missense Mutation (SNP) | VAF 405/895 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); catalogued as rs750318685; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOTCH4 | c.1044del p.G349Afs*49 | Frame Shift Del (DEL) | VAF 438/1123 reads (39%) | catalogued as rs753855314, COSV66678383, COSV66681385; called by mutect2, pindel, varscan2
- NOXA1 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 242/508 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs777037361; called by muse, mutect2, varscan2
- NRXN3 | c.343G>A p.V115M (on ENST00000557594 / NM_001272020.2; = p.V747M on NM_004796.6) | Missense Mutation (SNP) | VAF 271/516 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs982170073, COSV55336026; called by muse, mutect2, varscan2
- NUP210 | c.5200G>A p.A1734T | Missense Mutation (SNP) | VAF 236/494 reads (48%) | SIFT tolerated (0.54); PolyPhen benign (0.038); catalogued as rs373258255; called by muse, mutect2, varscan2
- OBSCN | c.13108G>A p.A4370T | Missense Mutation (SNP) | VAF 484/959 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0.121); catalogued as rs534557072, COSV52833769; called by muse, mutect2, varscan2
- OCEL1 | c.115del p.R39Afs*11 | Frame Shift Del (DEL) | VAF 434/1000 reads (43%) | catalogued as COSV99285799; called by mutect2, pindel, varscan2
- OLIG1 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 36/1096 reads (3%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs1203516936; called by muse, mutect2
- OR10W1 | c.654G>T p.K218N | Missense Mutation (SNP) | VAF 253/557 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV67720164, COSV67720583; called by muse, mutect2, varscan2
- OR51T1 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 327/329 reads (99%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs781697460, COSV59025275; called by muse, mutect2, varscan2
- ORC6 | c.507dup p.A170Sfs*4 | Frame Shift Ins (INS) | VAF 144/324 reads (44%) | catalogued as rs35441257; called by mutect2, varscan2
- OSGEP | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 34/460 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.033); catalogued as rs375098598, COSV52831370; called by muse, mutect2
- OSGEPL1 | c.36del p.F12Lfs*12 | Frame Shift Del (DEL) | VAF 172/180 reads (96%) | catalogued as rs750679212; called by mutect2, varscan2
- PALD1 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 304/632 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1247625775; called by muse, mutect2, varscan2
- PARP9 | c.1547C>T p.A516V | Missense Mutation (SNP) | VAF 155/371 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs760164261; called by muse, mutect2
- PCDHA10 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 31/493 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.232); catalogued as rs1554148335, COSV56529523; called by muse, mutect2
- PCDHA11 | c.1375T>C p.Y459H | Missense Mutation (SNP) | VAF 334/675 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.451); catalogued as rs782114058; called by muse, mutect2, varscan2
- PCDHGA1 | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 176/399 reads (44%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.021); catalogued as COSV65295383, COSV65296145; called by muse, mutect2, varscan2
- PCDHGA12 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 201/410 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.052); catalogued as rs767521224, COSV52741799; called by muse, mutect2, varscan2
- PCDHGA7 | c.369A>G p.I123M | Missense Mutation (SNP) | VAF 215/422 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs773903039; called by muse, mutect2, varscan2
- PCK2 | c.91C>T p.R31* | Nonsense Mutation (SNP) | VAF 80/477 reads (17%) | catalogued as rs962594037, COSV53749584; called by muse, mutect2, varscan2
- PCNT | c.2776G>A p.A926T | Missense Mutation (SNP) | VAF 40/868 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as rs1044689927, COSV64033710; called by muse, mutect2
- PDLIM4 | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 285/605 reads (47%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.795); catalogued as rs867265087, COSV53803954, COSV99516804; called by muse, mutect2, varscan2
- PDPN | c.274G>A p.A92T (on ENST00000621990; = p.A168T on NM_006474.4) | Missense Mutation (SNP) | VAF 135/291 reads (46%) | SIFT tolerated (0.51); PolyPhen benign (0.027); catalogued as rs532394472, COSV53850814; called by muse, mutect2, varscan2
- PDZD9 | c.518A>G p.H173R (on ENST00000424898 / NM_001363519.1; = p.H113R on NM_173806.4) | Missense Mutation (SNP) | VAF 202/429 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1305866132; called by muse, mutect2, varscan2
- PENK | c.502G>T p.E168* | Nonsense Mutation (SNP) | VAF 110/1449 reads (8%) | catalogued as COSV59242323; called by muse, mutect2
- PGAP6 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 322/834 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.732); catalogued as rs768450549, COSV51741052; called by muse, varscan2
- PHACTR3 | c.695del p.P232Hfs*30 | Frame Shift Del (DEL) | VAF 630/1209 reads (52%) | catalogued as COSV63028198; called by mutect2, pindel, varscan2
- PHTF2 | c.1447A>G p.S483G (on ENST00000248550 / NM_001366089.1; = p.S445G on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.937); catalogued as rs1481078262; called by muse, varscan2
- PIH1D1 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 356/356 reads (100%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.803); catalogued as COSV51807016; called by muse, mutect2, varscan2
- PIK3CB | c.137T>C p.V46A | Missense Mutation (SNP) | VAF 168/344 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.585); catalogued as COSV56687321; called by muse, mutect2, varscan2
- PLD3 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 684/684 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs940601505, COSV99396458; called by muse, mutect2, varscan2
- PLEC | c.11485G>A p.V3829M (on ENST00000322810 / NM_201380.4; = p.V3719M on NM_000445.5) | Missense Mutation (SNP) | VAF 118/1756 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as rs201892506, COSV59708991; called by muse, mutect2
- PLEKHA5 | c.929dup p.N310Kfs*8 | Frame Shift Ins (INS) | VAF 196/204 reads (96%) | catalogued as rs1565550899; called by mutect2, varscan2
- PLEKHH1 | c.3999dup p.T1334Hfs*56 | Frame Shift Ins (INS) | VAF 220/484 reads (45%) | catalogued as rs761759640; called by mutect2, varscan2
- POGK | c.689del p.N230Tfs*8 | Frame Shift Del (DEL) | VAF 299/766 reads (39%) | catalogued as COSV63312096; called by mutect2, pindel, varscan2
- POLD3 | c.898del p.R300Gfs*5 | Frame Shift Del (DEL) | VAF 110/224 reads (49%) | catalogued as rs761423306, COSV55240660; called by mutect2, varscan2
- PPARA | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 258/615 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs766370613, COSV53079008, COSV53080338; called by muse, mutect2
- PPCS | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 25/601 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1482478128, COSV65333597; called by muse, mutect2
- PPM1K | c.462_464del p.K154del | In Frame Del (DEL) | VAF 112/244 reads (46%) | catalogued as rs1269842628; called by pindel, varscan2
- PPME1 | c.124T>C p.S42P | Missense Mutation (SNP) | VAF 128/333 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs148853537; called by muse, mutect2, varscan2
- PPP1R13L | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 454/456 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1473770382; called by muse, mutect2, varscan2
- PPP1R16A | c.1333dup p.H445Pfs*14 | Frame Shift Ins (INS) | VAF 444/2079 reads (21%) | catalogued as rs777096925; called by mutect2, pindel, varscan2
- PREX2 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 152/566 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs866864487, COSV55780007; called by muse, mutect2, varscan2
- PROS1 | c.563del p.N188Mfs*20 | Frame Shift Del (DEL) | VAF 154/352 reads (44%) | catalogued as rs753544869; called by mutect2, pindel, varscan2
- PSD | c.750dup p.S251Qfs*5 | Frame Shift Ins (INS) | VAF 190/403 reads (47%) | catalogued as rs761494960; called by mutect2, varscan2
- PTPRF | c.5364G>A p.R1788= | Splice Region (SNP) | VAF 164/332 reads (49%) | catalogued as rs1324438993; called by muse, mutect2, varscan2
- PTPRQ | c.5901dup p.A1968Cfs*24 (on ENST00000616559; = p.A1926Cfs*24 on NM_001145026.2) | Frame Shift Ins (INS) | VAF 122/338 reads (36%) | catalogued as rs1174298545; called by mutect2, pindel, varscan2
- PTPRT | c.2598A>T p.Q866H | Missense Mutation (SNP) | VAF 299/987 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61978809; called by muse, mutect2, varscan2
- QARS1 | c.633C>T p.G211= | Splice Region (SNP) | VAF 187/386 reads (48%) | catalogued as rs752655908; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- R3HCC1L | c.218T>A p.I73N | Missense Mutation (SNP) | VAF 14/397 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as COSV54401763; called by muse, mutect2
- RAB10 | c.539A>G p.N180S | Missense Mutation (SNP) | VAF 159/368 reads (43%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs758384060; called by muse, mutect2, varscan2
- RAB3GAP2 | c.1042G>T p.G348C | Missense Mutation (SNP) | VAF 140/282 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV52966810; called by mutect2, varscan2
- RABEP2 | c.1328G>A p.R443Q | Missense Mutation (SNP) | VAF 373/785 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.695); catalogued as rs775196829; called by muse, mutect2, varscan2
- RAG2 | c.1524dup p.G509Rfs*15 | Frame Shift Ins (INS) | VAF 193/277 reads (70%) | catalogued as rs751978214; called by mutect2, pindel, varscan2
- RALYL | c.366C>T p.G122= | Splice Region (SNP) | VAF 116/370 reads (31%) | catalogued as rs182622234, COSV72818112; called by muse, mutect2, varscan2
- RASA3 | c.1370_1372del p.F457del | In Frame Del (DEL) | VAF 203/424 reads (48%) | catalogued as rs767949177; called by pindel, varscan2
- RBM20 | c.1222del p.L408Sfs*17 | Frame Shift Del (DEL) | VAF 251/654 reads (38%) | catalogued as COSV65704142; called by mutect2, pindel, varscan2
- RCBTB2 | c.298dup p.I100Nfs*27 | Frame Shift Ins (INS) | VAF 194/414 reads (47%) | catalogued as rs767856805; called by mutect2, varscan2
- RCCD1 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 185/402 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0.02); catalogued as rs139606108; called by muse, mutect2, varscan2
- RFC1 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 135/288 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376166947; called by muse, mutect2, varscan2
- RFX7 | c.2777C>T p.P926L (on ENST00000559447 / NM_001368074.1; = p.P1023L on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 274/274 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100428385, COSV57963129; called by muse, mutect2, varscan2
- RGL4 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 248/536 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.148); catalogued as rs374014694; called by muse, mutect2, varscan2
- RHBDD3 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 430/887 reads (48%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs530526042; called by muse, mutect2, varscan2
- RHBDF2 | c.932dup p.L312Tfs*52 | Frame Shift Ins (INS) | VAF 224/532 reads (42%) | catalogued as rs756639910; called by mutect2, varscan2
- RIMS2 | c.3721G>A p.D1241N | Missense Mutation (SNP) | VAF 26/730 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs959651634; called by muse, mutect2
- RIPK4 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 234/496 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1171215367; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 265/709 reads (37%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNFT1 | c.704del p.L235* | Frame Shift Del (DEL) | VAF 102/259 reads (39%) | catalogued as COSV59869927; called by mutect2, pindel, varscan2
- ROGDI | c.595C>T p.L199F | Missense Mutation (SNP) | VAF 271/595 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762068973; called by muse, mutect2, varscan2
- RREB1 | c.3907C>T p.R1303C | Missense Mutation (SNP) | VAF 356/780 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs1308515141; called by muse, mutect2, varscan2
- RS1 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 60/189 reads (32%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs374672514, COSV66105794; called by muse, mutect2, varscan2
- RSAD2 | c.1014T>A p.F338L | Missense Mutation (SNP) | VAF 20/592 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101150018; called by muse, mutect2
- RTCB | c.736dup p.M246Nfs*6 | Frame Shift Ins (INS) | VAF 196/429 reads (46%) | catalogued as rs771992011; called by mutect2, varscan2
- RYR2 | c.14368C>T p.R4790* | Nonsense Mutation (SNP) | VAF 106/240 reads (44%) | catalogued as COSV63702045; called by muse, varscan2
- SACS | c.11809A>G p.N3937D | Missense Mutation (SNP) | VAF 253/549 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.09); catalogued as rs1480129736; called by muse, mutect2, varscan2
- SALL3 | c.906del p.G303Afs*92 | Frame Shift Del (DEL) | VAF 34/86 reads (40%) | catalogued as rs1424702195; called by mutect2, pindel, varscan2
- SAMD11 | c.1005dup p.A336Rfs*119 | Frame Shift Ins (INS) | VAF 179/468 reads (38%) | catalogued as rs1410048057; called by mutect2, pindel, varscan2
- SAMD4A | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 83/471 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.448); catalogued as rs778052233, COSV51880189; called by muse, mutect2, varscan2
- SAMHD1 | c.286del p.E96Rfs*20 | Frame Shift Del (DEL) | VAF 156/584 reads (27%) | catalogued as COSV99483707; called by mutect2, pindel, varscan2
- SBSPON | c.454C>T p.R152* | Nonsense Mutation (SNP) | VAF 174/926 reads (19%) | catalogued as rs750912392, COSV52076656; called by muse, varscan2
- SCAF11 | c.3845del p.P1282Lfs*29 | Frame Shift Del (DEL) | VAF 138/345 reads (40%) | catalogued as rs764655538; called by mutect2, pindel, varscan2
- SCAP | c.1619G>A p.R540H | Missense Mutation (SNP) | VAF 112/668 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as rs754966611, COSV55562555; called by muse, mutect2, varscan2
- SCG5 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 348/350 reads (99%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.019); catalogued as rs200869533; called by muse, mutect2, varscan2
- SEC24D | c.2029C>A p.L677I | Missense Mutation (SNP) | VAF 78/191 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as rs1353251933; called by muse, mutect2, varscan2
- SEC62 | c.429del p.D144Mfs*58 | Frame Shift Del (DEL) | VAF 30/176 reads (17%) | catalogued as rs751191303; called by mutect2, varscan2
- SERPINB5 | c.412G>T p.D138Y | Missense Mutation (SNP) | VAF 113/292 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.723); catalogued as COSV101237620; called by muse, mutect2, varscan2
- SH2D3C | c.2129G>A p.R710Q (on ENST00000314830 / NM_170600.3; = p.R553Q on NM_005489.4) | Missense Mutation (SNP) | VAF 194/466 reads (42%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.999); catalogued as rs752313584, COSV59126905; called by muse, mutect2, varscan2
- SH3RF2 | c.635T>C p.L212P | Missense Mutation (SNP) | VAF 176/361 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751741883; called by muse, mutect2, varscan2
- SHC3 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 388/792 reads (49%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as rs746708767; called by muse, varscan2
- SHOC1 | c.931A>G p.M311V | Missense Mutation (SNP) | VAF 157/288 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100597555; called by muse, mutect2, varscan2
- SI | c.4432A>G p.R1478G | Missense Mutation (SNP) | VAF 83/334 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1175510343; called by muse, mutect2, varscan2
- SIPA1L3 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 898/1224 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as rs767672961, COSV55914125; called by muse, mutect2
- SLC17A2 | c.361dup p.M121Nfs*21 | Frame Shift Ins (INS) | VAF 150/372 reads (40%) | catalogued as rs770669846; called by mutect2, varscan2
- SLC17A7 | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 661/663 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as rs535780422, COSV55546736; called by muse, mutect2, varscan2
- SLC1A1 | c.68C>A p.S23Y | Missense Mutation (SNP) | VAF 68/764 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs770393000; called by muse, mutect2
- SLC25A32 | c.883A>G p.I295V | Missense Mutation (SNP) | VAF 259/707 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.669); catalogued as COSV52568760; called by muse, mutect2, varscan2
- SLC2A2 | c.937G>T p.A313S | Missense Mutation (SNP) | VAF 75/408 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.138); catalogued as rs1324205444, COSV58588755; called by muse, mutect2, varscan2
- SLC38A9 | c.934dup p.S312Ffs*4 | Frame Shift Ins (INS) | VAF 133/269 reads (49%) | catalogued as rs753030864; called by mutect2, varscan2
- SLC7A6 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 297/699 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54718366; called by muse, mutect2, varscan2
- SLC9A3 | c.1312G>A p.V438I | Missense Mutation (SNP) | VAF 283/920 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.656); catalogued as rs375784344; called by muse, mutect2, varscan2
- SLF2 | c.3476G>A p.R1159Q | Missense Mutation (SNP) | VAF 174/395 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs770442229, COSV53276063; called by muse, mutect2, varscan2
- SMAD6 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 168/397 reads (42%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs201098141, COSV56597518; called by muse, mutect2, varscan2
- SMC2 | c.1663G>T p.D555Y | Missense Mutation (SNP) | VAF 36/340 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99658617; called by muse, mutect2
- SMG1 | c.2245G>A p.A749T | Missense Mutation (SNP) | VAF 46/349 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs769154556, COSV67171034; called by muse, mutect2, varscan2
- SMG6 | c.2524A>G p.T842A | Missense Mutation (SNP) | VAF 528/528 reads (100%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs750155315; called by muse, mutect2, varscan2
- SMR3A | c.326C>A p.P109Q | Missense Mutation (SNP) | VAF 240/538 reads (45%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.988); catalogued as rs763076642, COSV56951466; called by muse, mutect2, varscan2
- SNRNP200 | c.604A>G p.N202D | Missense Mutation (SNP) | VAF 29/244 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV60492629; called by muse, varscan2
- SNX15 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 100/581 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs576005811, COSV57246494; called by muse, mutect2, varscan2
- SOX11 | c.650T>C p.V217A | Missense Mutation (SNP) | VAF 298/622 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1309670314; called by muse, varscan2
- SPAG17 | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 185/393 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as rs139343615; called by muse, mutect2, varscan2
- SPAG17 | c.282del p.K94Nfs*3 | Frame Shift Del (DEL) | VAF 119/302 reads (39%) | catalogued as rs771461785; called by mutect2, pindel, varscan2
- SPATA31A3 | c.3574dup p.T1192Nfs*14 | Frame Shift Ins (INS) | VAF 291/686 reads (42%) | catalogued as rs1301154937; called by mutect2, varscan2
- SPNS2 | c.1622C>T p.A541V | Missense Mutation (SNP) | VAF 634/635 reads (100%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs779414794, COSV54606682; called by muse, mutect2, varscan2
- SPOCK3 | c.136A>G p.T46A | Missense Mutation (SNP) | VAF 256/260 reads (98%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as rs755016780; called by muse, mutect2, varscan2
- SPON2 | c.602A>G p.N201S | Missense Mutation (SNP) | VAF 410/848 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as rs1209582870; called by muse, mutect2, varscan2
- SPTBN5 | c.7016G>A p.R2339Q | Missense Mutation (SNP) | VAF 56/292 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.114); catalogued as rs990360524, COSV58020412; called by muse, varscan2
- SREK1IP1 | c.381del p.K129Nfs*29 | Frame Shift Del (DEL) | VAF 169/338 reads (50%) | catalogued as rs1470980144, COSV72486131; called by mutect2, varscan2
- SRSF6 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 139/476 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as rs147863077; called by muse, mutect2, varscan2
- SS18L1 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 470/724 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59209665, COSV59210948; called by muse, mutect2, varscan2
- ST8SIA6 | c.753del p.A252Pfs*53 | Frame Shift Del (DEL) | VAF 144/152 reads (95%) | catalogued as rs758746672, COSV66468613; called by mutect2, varscan2
- STAU2 | c.1091del p.N364Mfs*67 (on ENST00000524300 / NM_001164380.2; = p.N332Mfs*67 on NM_014393.2) | Frame Shift Del (DEL) | VAF 169/698 reads (24%) | catalogued as rs746501298; called by mutect2, varscan2
- STRA6 | c.1772C>T p.A591V | Missense Mutation (SNP) | VAF 261/532 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs140894233; called by muse, varscan2
- STRADA | c.997del p.R333Gfs*42 (on ENST00000336174 / NM_001363786.1; = p.R296Gfs*58 on NM_153335.6) | Frame Shift Del (DEL) | VAF 78/454 reads (17%) | catalogued as rs762120842, COSV51992441; called by mutect2, varscan2
- STRC | c.455G>C p.G152A | Missense Mutation (SNP) | VAF 316/717 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.359); catalogued as rs763225240; called by muse, mutect2, varscan2
- SYNPO2 | c.2780C>A p.P927H | Missense Mutation (SNP) | VAF 232/594 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1239718386, COSV61114924; called by muse, mutect2, varscan2
- SYNPO2L | c.1495C>A p.L499M (on ENST00000394810 / NM_001114133.3; = p.L275M on NM_024875.5) | Missense Mutation (SNP) | VAF 52/691 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs754310220, COSV65736505; called by muse, mutect2
- SYTL5 | c.160G>A p.G54R | Missense Mutation (SNP) | VAF 16/360 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.099); catalogued as COSV52899966; called by muse, mutect2
- TAF15 | c.1763G>A p.R588H (on ENST00000605844 / NM_139215.3; = p.R585H on NM_003487.4) | Missense Mutation (SNP) | VAF 20/625 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs776503828; called by muse, mutect2
- TAF1L | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 313/631 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs756820373, COSV54257507, COSV99644464; called by muse, mutect2, varscan2
- TAF7L | c.1337dup p.N446Kfs*2 | Frame Shift Ins (INS) | VAF 132/132 reads (100%) | catalogued as rs780573926; called by mutect2, varscan2
- TAL1 | c.134C>A p.A45D | Missense Mutation (SNP) | VAF 36/1098 reads (3%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV53745362; called by muse, mutect2
- TAOK2 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 319/673 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as rs781600192, COSV54234458; called by muse, mutect2, varscan2
- TAOK3 | c.931dup p.I311Nfs*13 | Frame Shift Ins (INS) | VAF 167/359 reads (47%) | catalogued as rs1346340006; called by mutect2, varscan2
- TARBP2 | c.566G>A p.R189H (on ENST00000266987 / NM_134323.2; = p.R168H on NM_004178.4) | Missense Mutation (SNP) | VAF 38/552 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1317193037, COSV57199393; called by muse, mutect2
- TBC1D16 | c.1513dup p.E505Gfs*43 | Frame Shift Ins (INS) | VAF 157/397 reads (40%) | catalogued as rs759141475; called by mutect2, pindel, varscan2
- TCHH | c.4675G>A p.E1559K | Missense Mutation (SNP) | VAF 319/682 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.132); catalogued as rs201179054, COSV64276945; called by muse, mutect2, varscan2
- TCHH | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 230/492 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.961); catalogued as COSV64274704; called by muse, mutect2, varscan2
- TIGD7 | c.658G>A p.G220R | Missense Mutation (SNP) | VAF 239/509 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs372035499; called by muse, mutect2, varscan2
- TLE5 | c.370C>T p.R124* | Nonsense Mutation (SNP) | VAF 254/490 reads (52%) | catalogued as rs1225559792; called by muse, mutect2
- TMEM121B | c.1270C>A p.L424M | Missense Mutation (SNP) | VAF 465/955 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.976); catalogued as rs747913031; called by muse, mutect2, varscan2
- TMEM65 | c.425A>G p.H142R | Missense Mutation (SNP) | VAF 164/278 reads (59%) | SIFT tolerated (0.2); PolyPhen benign (0.089); catalogued as rs781601480; called by muse, mutect2, varscan2
- TNIP3 | c.624A>C p.E208D | Missense Mutation (SNP) | VAF 57/268 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99284653; called by muse, mutect2, varscan2
- TNKS | c.3662G>A p.S1221N | Missense Mutation (SNP) | VAF 28/596 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV60059288; called by muse, mutect2
- TNKS2 | c.1047dup p.H350Tfs*16 | Frame Shift Ins (INS) | VAF 232/544 reads (43%) | catalogued as rs1436960698; called by mutect2, pindel, varscan2
- TNNT2 | c.576G>A p.M192I | Missense Mutation (SNP) | VAF 207/417 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as rs763316865; called by muse, mutect2, varscan2
- TRAPPC8 | c.2037del p.F679Lfs*18 | Frame Shift Del (DEL) | VAF 150/307 reads (49%) | catalogued as rs770561785; called by mutect2, varscan2
- TRH | c.319del p.A107Lfs*23 | Frame Shift Del (DEL) | VAF 308/728 reads (42%) | catalogued as rs770451471, COSV57014685; called by mutect2, pindel, varscan2
- TRIO | c.7050dup p.V2351Rfs*90 | Frame Shift Ins (INS) | VAF 375/719 reads (52%) | catalogued as rs746654944; called by mutect2, varscan2
- TRIO | c.7511G>A p.G2504E | Missense Mutation (SNP) | VAF 170/1430 reads (12%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.986); catalogued as rs774871473; called by muse, varscan2
- TRUB1 | c.595dup p.L199Pfs*20 | Frame Shift Ins (INS) | VAF 136/286 reads (48%) | catalogued as rs762997509; called by mutect2, varscan2
- TSHZ1 | c.1086del p.C363Afs*14 (on ENST00000580243 / NM_001308210.2; = p.C318Afs*14 on NM_005786.6) | Frame Shift Del (DEL) | VAF 109/715 reads (15%) | catalogued as CX1110103; called by mutect2, pindel, varscan2
- TSHZ2 | c.2454dup p.M819Hfs*11 | Frame Shift Ins (INS) | VAF 278/972 reads (29%) | catalogued as rs1193207010; called by mutect2, varscan2
- TTN | c.2396C>T p.T799M (on ENST00000591111; = p.T753M on NM_003319.4) | Missense Mutation (SNP) | VAF 298/305 reads (98%) | PolyPhen benign (0.107); catalogued as rs149061352, COSV60000823; ClinVar: uncertain significance; called by muse, mutect2
- TTYH3 | c.1319G>A p.R440H | Missense Mutation (SNP) | VAF 455/892 reads (51%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1180699779, COSV51863414; called by muse, mutect2, varscan2
- TUBE1 | c.362A>G p.Q121R | Missense Mutation (SNP) | VAF 182/400 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782115613; called by muse, mutect2, varscan2
- TUT7 | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 222/579 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs766227229; called by muse, mutect2
- UBC | c.833T>C p.L278P | Missense Mutation (SNP) | VAF 294/698 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1442268922; called by muse, mutect2, varscan2
- UBL3 | c.103A>G p.I35V | Missense Mutation (SNP) | VAF 131/274 reads (48%) | SIFT tolerated (0.93); PolyPhen benign (0.092); catalogued as rs562596173; called by muse, mutect2, varscan2
- UCN3 | c.312G>C p.R104S | Missense Mutation (SNP) | VAF 116/352 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as rs781875175, COSV66823929; called by muse, mutect2, varscan2
- UGCG | c.1094dup p.L365Ffs*36 | Frame Shift Ins (INS) | VAF 186/440 reads (42%) | catalogued as rs1243652090; called by mutect2, varscan2
- UGGT1 | c.1474A>G p.I492V | Missense Mutation (SNP) | VAF 120/375 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.194); catalogued as rs757746933; called by muse, mutect2, varscan2
- ULBP1 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 62/377 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as rs769275822, COSV99998097; called by muse, mutect2, varscan2
- UROC1 | c.1438G>A p.V480M | Missense Mutation (SNP) | VAF 236/438 reads (54%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.935); catalogued as COSV52034713, COSV99330729; called by muse, mutect2, varscan2
- UST | c.1117del p.L373* | Frame Shift Del (DEL) | VAF 294/596 reads (49%) | catalogued as rs760552029, COSV66551382; called by mutect2, varscan2
- UVSSA | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 244/525 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.036); catalogued as rs188017443, COSV101104352; called by muse, mutect2, varscan2
- VIPAS39 | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 63/381 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.681); catalogued as rs746475339, COSV58940163; called by muse, mutect2, varscan2
- VIRMA | c.1290G>C p.Q430H | Missense Mutation (SNP) | VAF 296/830 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); catalogued as COSV52584375; called by muse, mutect2, varscan2
- VPS13A | c.1115del p.K372Sfs*2 | Frame Shift Del (DEL) | VAF 148/335 reads (44%) | catalogued as rs770350986; called by mutect2, varscan2
- VPS13B | c.4640T>G p.I1547S | Missense Mutation (SNP) | VAF 419/699 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV62144850; called by muse, mutect2, varscan2
- VPS9D1 | c.1805A>G p.Y602C | Missense Mutation (SNP) | VAF 164/358 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); catalogued as rs566042318; called by muse, mutect2, varscan2
- VWC2 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 392/836 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs574589537; called by muse, mutect2, varscan2
- WDR47 | c.241del p.R81Gfs*7 | Frame Shift Del (DEL) | VAF 127/291 reads (44%) | catalogued as rs1557951659, COSV63058584; called by mutect2, pindel, varscan2
- WDR64 | c.1270A>G p.N424D | Missense Mutation (SNP) | VAF 124/266 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1160533747; called by muse, varscan2
- WDR76 | c.817T>C p.W273R | Missense Mutation (SNP) | VAF 140/142 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs778295157; called by muse, varscan2
- WNK4 | c.1822del p.V608Cfs*53 | Frame Shift Del (DEL) | VAF 350/868 reads (40%) | catalogued as rs762079039; called by mutect2, pindel, varscan2
- XAB2 | c.793T>C p.Y265H | Missense Mutation (SNP) | VAF 102/497 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs202178945; called by muse, mutect2, varscan2
- XRCC1 | c.1514del p.P505Lfs*73 | Frame Shift Del (DEL) | VAF 93/696 reads (13%) | catalogued as COSV99486820; called by mutect2, pindel, varscan2
- ZAR1 | c.57dup p.C20Lfs*332 | Frame Shift Ins (INS) | VAF 382/760 reads (50%) | catalogued as rs757396573; called by mutect2, varscan2
- ZBED9 | c.187A>G p.T63A | Missense Mutation (SNP) | VAF 400/766 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs931069099; called by muse, mutect2, varscan2
- ZBTB39 | c.1997G>T p.C666F | Missense Mutation (SNP) | VAF 124/717 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761987467; called by muse, mutect2, varscan2
- ZBTB40 | c.792dup p.L265Tfs*8 | Frame Shift Ins (INS) | VAF 112/272 reads (41%) | catalogued as rs775262758; called by mutect2, varscan2
- ZBTB7C | c.403dup p.E135Gfs*4 | Frame Shift Ins (INS) | VAF 164/514 reads (32%) | catalogued as rs747456682; called by mutect2, varscan2
- ZFHX3 | c.4187G>A p.R1396H | Missense Mutation (SNP) | VAF 38/734 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as rs774988278, COSV51742009; called by muse, mutect2
- ZFHX4 | c.6162_6165del p.P2056Hfs*26 | Frame Shift Del (DEL) | VAF 152/646 reads (24%) | catalogued as rs1554575033; called by pindel, varscan2
- ZFP28 | c.2557G>T p.D853Y | Missense Mutation (SNP) | VAF 133/600 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.67); catalogued as COSV100019617; called by muse, mutect2, varscan2
- ZFP82 | c.1250T>C p.I417T | Missense Mutation (SNP) | VAF 526/752 reads (70%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as rs908269233, COSV101089295; called by muse, mutect2, varscan2
- ZHX1 | c.2269C>T p.R757C | Missense Mutation (SNP) | VAF 349/972 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs747135351, COSV52876504; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 252/520 reads (48%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as rs781576038; called by muse, mutect2, varscan2
- ZNF133 | c.911G>T p.G304V (on ENST00000316358 / NM_001352454.2; = p.G303V on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 232/533 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60367852; called by muse, mutect2, varscan2
- ZNF211 | c.1222C>T p.R408* (on ENST00000347302 / NM_198855.4; = p.R421* on NM_006385.5) | Nonsense Mutation (SNP) | VAF 313/668 reads (47%) | catalogued as rs775009360; called by muse, mutect2, varscan2
- ZNF234 | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 423/424 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV70603142; called by muse, varscan2
- ZNF318 | c.3738del p.A1247Lfs*13 | Frame Shift Del (DEL) | VAF 225/626 reads (36%) | catalogued as COSV100545892; called by pindel, varscan2
- ZNF347 | c.970A>G p.K324E | Missense Mutation (SNP) | VAF 656/656 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.234); catalogued as COSV61968904; called by muse, mutect2, varscan2
- ZNF668 | c.1543del p.Q515Sfs*14 | Frame Shift Del (DEL) | VAF 132/908 reads (15%) | catalogued as rs760397907; called by mutect2, pindel, varscan2
- ZNF736 | c.512A>G p.K171R | Missense Mutation (SNP) | VAF 68/385 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as rs553514851; called by muse, mutect2, varscan2
- ZNF831 | c.2785C>T p.L929F | Missense Mutation (SNP) | VAF 140/1284 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs1174650295, COSV100926119; called by muse, varscan2
- ZNF93 | c.183dup p.P62Tfs*8 | Frame Shift Ins (INS) | VAF 130/265 reads (49%) | catalogued as rs781728912; called by mutect2, varscan2
- ZSWIM3 | c.408del p.D137Tfs*16 | Frame Shift Del (DEL) | VAF 264/910 reads (29%) | catalogued as rs1426206799; called by mutect2, varscan2
- A2ML1 | c.1027A>G p.T343A | Missense Mutation (SNP) | VAF 141/141 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ABCA10 | c.93del p.K31Nfs*18 | Frame Shift Del (DEL) | VAF 199/488 reads (41%) | called by mutect2, pindel, varscan2
- ABCA12 | c.2181dup p.A728Sfs*10 (on ENST00000272895 / NM_173076.3; = p.A410Sfs*10 on NM_015657.3) | Frame Shift Ins (INS) | VAF 388/539 reads (72%) | called by mutect2, pindel, varscan2
- ABCA3 | c.1572G>T p.E524D | Missense Mutation (SNP) | VAF 260/558 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.119); called by muse, varscan2
- ABCC5 | c.235G>T p.G79* | Nonsense Mutation (SNP) | VAF 15/239 reads (6%) | called by muse, mutect2
- ACAD10 | c.2181dup p.Y728Ifs*15 | Frame Shift Ins (INS) | VAF 225/582 reads (39%) | called by mutect2, pindel, varscan2
- ACAD10 | c.2932G>C p.A978P | Missense Mutation (SNP) | VAF 282/586 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ACSM1 | c.908T>A p.I303K | Missense Mutation (SNP) | VAF 124/271 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ACSM2A | c.818T>C p.L273P (on ENST00000219054; = p.L194P on NM_001308169.2) | Missense Mutation (SNP) | VAF 248/535 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ADAMTS1 | c.346C>A p.P116T | Missense Mutation (SNP) | VAF 62/769 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.044); called by muse, mutect2
- ADAMTS10 | c.1699G>C p.V567L | Missense Mutation (SNP) | VAF 35/770 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2
- ADARB2 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 24/488 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.259); called by muse, mutect2
- ADCY10 | c.4418A>G p.H1473R | Missense Mutation (SNP) | VAF 184/408 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ADD1 | c.1213A>T p.K405* | Nonsense Mutation (SNP) | VAF 271/505 reads (54%) | called by muse, mutect2, varscan2
- ADGRB3 | c.4298G>T p.R1433M | Missense Mutation (SNP) | VAF 20/320 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- ADGRG1 | c.1135T>C p.C379R | Missense Mutation (SNP) | VAF 306/640 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ADGRL3 | c.2200G>A p.A734T (on ENST00000506720 / NM_001322402.2; = p.A666T on NM_015236.6) | Missense Mutation (SNP) | VAF 288/570 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- AHDC1 | c.2462C>T p.A821V | Missense Mutation (SNP) | VAF 48/974 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0.025); called by muse, mutect2
- AKAP9 | c.842A>T p.D281V | Missense Mutation (SNP) | VAF 174/406 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- ALDH1L1 | c.393del p.S133Pfs*28 | Frame Shift Del (DEL) | VAF 186/498 reads (37%) | called by mutect2, pindel, varscan2
- ALG1 | c.398dup p.G134Rfs*4 | Frame Shift Ins (INS) | VAF 185/430 reads (43%) | called by mutect2, pindel, varscan2
- ALKBH7 | c.7G>T p.G3W | Missense Mutation (SNP) | VAF 239/530 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- AMER2 | c.426del p.R143Efs*25 | Frame Shift Del (DEL) | VAF 214/531 reads (40%) | called by mutect2, pindel, varscan2
- AMER3 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 695/705 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AMPD1 | c.168del p.V57Cfs*65 | Frame Shift Del (DEL) | VAF 178/444 reads (40%) | called by mutect2, pindel, varscan2
- AMZ2 | c.731T>C p.L244S | Missense Mutation (SNP) | VAF 98/228 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ANK2 | c.8211del p.D2738Ifs*6 | Frame Shift Del (DEL) | VAF 120/335 reads (36%) | called by mutect2, pindel, varscan2
- ANK3 | c.10756A>G p.R3586G | Missense Mutation (SNP) | VAF 106/717 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ANKRD11 | c.5852C>T p.A1951V | Missense Mutation (SNP) | VAF 434/861 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKRD30A | c.683A>C p.N228T (on ENST00000611781; = p.N172T on NM_052997.2) | Missense Mutation (SNP) | VAF 176/177 reads (99%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ANKRD31 | c.1533dup p.G512Rfs*5 | Frame Shift Ins (INS) | VAF 140/284 reads (49%) | called by mutect2, varscan2
- ANKRD33 | c.680A>G p.Q227R (on ENST00000340970 / NM_001304459.2; = p.S419G on NM_182608.4) | Missense Mutation (SNP) | VAF 369/685 reads (54%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD36 | c.2498A>T p.D833V | Missense Mutation (SNP) | VAF 132/623 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- ANKRD60 | c.356G>T p.R119L | Missense Mutation (SNP) | VAF 305/991 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- ANKRD60 | c.24del p.M9Cfs*108 | Frame Shift Del (DEL) | VAF 32/81 reads (40%) | called by mutect2, pindel, varscan2
- ANKRD65 | c.1033C>T p.R345* | Nonsense Mutation (SNP) | VAF 31/1037 reads (3%) | called by muse, mutect2
- ANKS6 | c.1801G>A p.G601S | Missense Mutation (SNP) | VAF 267/523 reads (51%) | SIFT tolerated (0.96); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ANO4 | c.418A>G p.R140G (on ENST00000392977 / NM_001286615.2; = p.R105G on NM_178826.4) | Missense Mutation (SNP) | VAF 22/444 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.035); called by muse, mutect2
- AOC2 | c.1769C>T p.T590I | Missense Mutation (SNP) | VAF 24/801 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.589); called by muse, mutect2
- APC2 | c.4245del p.R1416Gfs*164 | Frame Shift Del (DEL) | VAF 513/1323 reads (39%) | called by mutect2, pindel, varscan2
- APOB | c.3565del p.M1189* | Frame Shift Del (DEL) | VAF 437/610 reads (72%) | called by mutect2, pindel, varscan2
- ARAP1 | c.4337T>G p.L1446R (on ENST00000393609 / NM_001040118.2; = p.L1201R on NM_015242.4) | Missense Mutation (SNP) | VAF 238/509 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- ARHGAP17 | c.2479A>G p.T827A (on ENST00000289968 / NM_001006634.3; = p.T749A on NM_018054.6) | Missense Mutation (SNP) | VAF 70/581 reads (12%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP24 | c.1697A>G p.E566G (on ENST00000395184 / NM_001025616.3; = p.E473G on NM_031305.3) | Missense Mutation (SNP) | VAF 293/475 reads (62%) | SIFT tolerated (0.15); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- ARHGAP28 | c.1216T>C p.F406L (on ENST00000383472 / NM_001366230.1; = p.F247L on NM_001010000.3) | Missense Mutation (SNP) | VAF 113/272 reads (42%) | SIFT tolerated (0.61); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ARHGEF28 | c.1756G>A p.A586T | Missense Mutation (SNP) | VAF 20/391 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.031); called by muse, mutect2
- ARID1A | c.6420dup p.F2141Lfs*9 | Frame Shift Ins (INS) | VAF 298/816 reads (37%) | called by pindel, varscan2
- ASB4 | c.634del p.L212Wfs*59 | Frame Shift Del (DEL) | VAF 294/777 reads (38%) | called by mutect2, pindel, varscan2
- ASH1L | c.7430A>C p.K2477T (on ENST00000368346 / NM_001366177.2; = p.K2472T on NM_018489.3) | Missense Mutation (SNP) | VAF 162/300 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ASIC4 | c.926G>A p.G309D | Missense Mutation (SNP) | VAF 501/508 reads (99%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ASTN2 | c.14G>A p.G5D | Missense Mutation (SNP) | VAF 104/174 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ASXL3 | c.1576C>T p.P526S | Missense Mutation (SNP) | VAF 53/464 reads (11%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASXL3 | c.1763T>A p.I588N | Missense Mutation (SNP) | VAF 246/463 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- ATP2B4 | c.1333A>G p.N445D | Missense Mutation (SNP) | VAF 182/369 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ATRNL1 | c.56T>C p.V19A | Missense Mutation (SNP) | VAF 419/872 reads (48%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATXN7L1 | c.2336dup p.R780Afs*2 | Frame Shift Ins (INS) | VAF 272/688 reads (40%) | called by mutect2, pindel, varscan2
- AVIL | c.1283A>G p.Y428C | Missense Mutation (SNP) | VAF 19/625 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AWAT1 | c.95dup p.L32Ffs*64 | Frame Shift Ins (INS) | VAF 210/294 reads (71%) | called by mutect2, pindel, varscan2
- AZI2 | c.1016A>G p.Y339C | Missense Mutation (SNP) | VAF 235/465 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- B3GNT7 | c.453G>T p.E151D | Missense Mutation (SNP) | VAF 93/1038 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.529); called by muse, mutect2
- BAZ1A | c.597del p.E200Nfs*25 | Frame Shift Del (DEL) | VAF 117/303 reads (39%) | called by mutect2, pindel, varscan2
- BCHE | c.1791A>C p.E597D | Missense Mutation (SNP) | VAF 35/301 reads (12%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- BCHE | c.758del p.G253Dfs*9 | Frame Shift Del (DEL) | VAF 87/435 reads (20%) | called by mutect2, pindel*, varscan2
- BCKDHB | c.518A>T p.D173V | Missense Mutation (SNP) | VAF 209/425 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- BLM | c.3651del p.K1217Nfs*62 | Frame Shift Del (DEL) | VAF 200/534 reads (37%) | called by mutect2, pindel, varscan2
- BMPR1B | c.1069T>G p.F357V | Missense Mutation (SNP) | VAF 133/231 reads (58%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- BNC2 | c.129G>T p.E43D | Missense Mutation (SNP) | VAF 103/206 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, varscan2
- BTAF1 | c.140T>C p.V47A | Missense Mutation (SNP) | VAF 67/170 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- C16orf46 | c.365dup p.E124Rfs*25 | Frame Shift Ins (INS) | VAF 307/797 reads (39%) | called by mutect2, pindel, varscan2
- C17orf50 | c.281del p.G94Afs*6 | Frame Shift Del (DEL) | VAF 575/1316 reads (44%) | called by mutect2, pindel, varscan2
- C17orf80 | c.374dup p.N125Kfs*3 | Frame Shift Ins (INS) | VAF 183/447 reads (41%) | called by mutect2, pindel, varscan2
- C19orf44 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 87/649 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C2 | c.758T>C p.L253P | Missense Mutation (SNP) | VAF 374/724 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C5orf34 | c.1864del p.T622Pfs*? | Frame Shift Del (DEL) | VAF 300/553 reads (54%) | called by mutect2, pindel, varscan2
- C8orf34 | c.997C>T p.L333F | Missense Mutation (SNP) | VAF 612/871 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C8orf48 | c.484_485dup p.D162Efs*13 | Frame Shift Ins (INS) | VAF 216/430 reads (50%) | called by mutect2, varscan2
- CACHD1 | c.274dup p.I92Nfs*52 | Frame Shift Ins (INS) | VAF 164/340 reads (48%) | called by mutect2, varscan2
- CACNA2D3 | c.3223G>C p.A1075P | Missense Mutation (SNP) | VAF 28/532 reads (5%) | SIFT tolerated (0.6); PolyPhen benign (0.006); called by muse, mutect2
- CAMK2B | c.1408C>A p.L470I | Missense Mutation (SNP) | VAF 175/325 reads (54%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CAMK2D | c.629G>T p.G210V | Missense Mutation (SNP) | VAF 144/261 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAMSAP3 | c.2425del p.H809Tfs*180 | Frame Shift Del (DEL) | VAF 374/937 reads (40%) | called by mutect2, pindel, varscan2
- CAMSAP3 | c.3589A>G p.M1197V | Missense Mutation (SNP) | VAF 437/928 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CAPN14 | c.224dup p.E76Gfs*54 | Frame Shift Ins (INS) | VAF 286/674 reads (42%) | called by mutect2, pindel, varscan2
- CARD14 | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 254/596 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CARS2 | c.1607A>G p.H536R | Missense Mutation (SNP) | VAF 288/598 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- CASD1 | c.2347del p.C783Vfs*21 | Frame Shift Del (DEL) | VAF 142/362 reads (39%) | called by mutect2, pindel, varscan2
- CASP8 | c.365T>G p.F122C (on ENST00000432109 / NM_033355.3; = p.F154C on NM_001228.4) | Missense Mutation (SNP) | VAF 312/313 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CC2D1B | c.1898A>C p.K633T | Missense Mutation (SNP) | VAF 24/630 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); called by muse, mutect2
- CCDC102B | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 61/371 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- CCDC151 | c.903A>G p.I301M | Missense Mutation (SNP) | VAF 258/586 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- CCDC172 | c.350A>G p.N117S | Missense Mutation (SNP) | VAF 82/197 reads (42%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- CCDC174 | c.539T>C p.L180S | Missense Mutation (SNP) | VAF 238/500 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- CCDC18 | c.290dup p.P98Afs*4 | Frame Shift Ins (INS) | VAF 93/195 reads (48%) | called by mutect2, varscan2
- CCDC183 | c.215dup p.A73Gfs*117 | Frame Shift Ins (INS) | VAF 263/657 reads (40%) | called by mutect2, pindel, varscan2
- CCDC81 | c.509T>G p.L170R | Missense Mutation (SNP) | VAF 107/222 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- CCL22 | c.249G>T p.W83C | Missense Mutation (SNP) | VAF 192/384 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- CCT6A | c.835dup p.R279Kfs*9 | Frame Shift Ins (INS) | VAF 93/304 reads (31%) | called by pindel, varscan2
- CDH23 | c.522del p.S175Pfs*15 | Frame Shift Del (DEL) | VAF 315/791 reads (40%) | called by mutect2, pindel, varscan2
- CDH8 | c.55T>A p.L19I | Missense Mutation (SNP) | VAF 255/510 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDK5RAP1 | c.956A>T p.N319I (on ENST00000357886 / NM_001365728.1; = p.N305I on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 327/535 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDRT15 | c.348_349dup p.A117Efs*114 | Frame Shift Ins (INS) | VAF 90/546 reads (16%) | called by mutect2, varscan2
- CDV3 | c.272_273del p.K91Rfs*3 | Frame Shift Del (DEL) | VAF 137/313 reads (44%) | called by mutect2, pindel, varscan2
- CDX1 | c.574G>T p.G192W | Missense Mutation (SNP) | VAF 24/463 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- CELF3 | c.1145T>C p.I382T | Missense Mutation (SNP) | VAF 209/439 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- CEP162 | c.2581dup p.R861Kfs*7 | Frame Shift Ins (INS) | VAF 133/351 reads (38%) | called by mutect2, pindel, varscan2
- CFAP46 | c.833A>G p.N278S | Missense Mutation (SNP) | VAF 201/457 reads (44%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.497); called by muse, mutect2
- CFAP58 | c.2608dup p.M870Nfs*6 | Frame Shift Ins (INS) | VAF 166/402 reads (41%) | called by mutect2, pindel, varscan2
- CFAP61 | c.2756C>T p.S919F | Missense Mutation (SNP) | VAF 303/601 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- CFAP97 | c.1336C>T p.L446F | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CHD1L | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 24/308 reads (8%) | SIFT tolerated (0.98); PolyPhen benign (0.001); called by muse, mutect2
- CHD8 | c.2699A>G p.Q900R (on ENST00000646647 / NM_001170629.2; = p.Q621R on NM_020920.4) | Missense Mutation (SNP) | VAF 150/317 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- CHEK1 | c.783del p.D262Ifs*42 | Frame Shift Del (DEL) | VAF 116/306 reads (38%) | called by mutect2, pindel, varscan2
- CHRM4 | c.121T>G p.S41A | Missense Mutation (SNP) | VAF 316/330 reads (96%) | SIFT tolerated (0.18); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- CILP | c.626T>C p.M209T | Missense Mutation (SNP) | VAF 214/215 reads (100%) | SIFT tolerated (0.36); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- CLEC16A | c.1832del p.L611Wfs*11 | Frame Shift Del (DEL) | VAF 122/399 reads (31%) | called by pindel, varscan2*
- CLIC6 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 220/568 reads (39%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.005); called by muse, varscan2
- CLN3 | c.1085G>A p.G362D (on ENST00000360019 / NM_001286104.2; = p.G386D on NM_000086.2) | Missense Mutation (SNP) | VAF 19/627 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CLOCK | c.2254T>G p.S752A | Missense Mutation (SNP) | VAF 73/584 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, varscan2
- CLTRN | c.85C>G p.L29V | Missense Mutation (SNP) | VAF 17/231 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.269); called by muse, mutect2
- CNR1 | c.380G>T p.G127V | Missense Mutation (SNP) | VAF 61/496 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CNTN1 | c.482del p.P161Hfs*14 | Frame Shift Del (DEL) | VAF 90/238 reads (38%) | called by mutect2, pindel, varscan2
- CNTN1 | c.747G>T p.K249N | Missense Mutation (SNP) | VAF 119/267 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- CNTN2 | c.451dup p.V151Gfs*6 | Frame Shift Ins (INS) | VAF 275/636 reads (43%) | called by mutect2, pindel, varscan2
- COL12A1 | c.1220T>C p.M407T | Missense Mutation (SNP) | VAF 249/452 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- COL18A1 | c.4564dup p.E1522Gfs*14 (on ENST00000359759 / NM_130444.3; = p.E1287Gfs*14 on NM_030582.4) | Frame Shift Ins (INS) | VAF 348/823 reads (42%) | called by mutect2, pindel, varscan2
- COL1A1 | c.1649A>G p.D550G | Missense Mutation (SNP) | VAF 322/632 reads (51%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- COL20A1 | c.1594T>G p.Y532D | Missense Mutation (SNP) | VAF 149/1267 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL22A1 | c.1622dup p.G542Wfs*23 | Frame Shift Ins (INS) | VAF 238/929 reads (26%) | called by pindel, varscan2
- COL27A1 | c.2447dup p.G817Wfs*8 | Frame Shift Ins (INS) | VAF 306/764 reads (40%) | called by mutect2, pindel, varscan2
- COL5A1 | c.4050del p.G1351Efs*137 | Frame Shift Del (DEL) | VAF 261/665 reads (39%) | called by mutect2, pindel, varscan2
- COL5A3 | c.4726dup p.C1576Lfs*18 | Frame Shift Ins (INS) | VAF 269/664 reads (41%) | called by mutect2, pindel, varscan2
- COLEC12 | c.2182T>G p.F728V | Missense Mutation (SNP) | VAF 240/512 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- COPB2 | c.418G>T p.G140* | Nonsense Mutation (SNP) | VAF 56/393 reads (14%) | called by muse, mutect2, varscan2
- COPS3 | c.537dup p.H180Tfs*20 | Frame Shift Ins (INS) | VAF 173/469 reads (37%) | called by mutect2, pindel, varscan2
- CPA4 | c.50G>A p.G17D | Missense Mutation (SNP) | VAF 127/310 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPEB3 | c.424C>T p.H142Y | Missense Mutation (SNP) | VAF 386/788 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- CPLANE1 | c.9279del p.K3093Nfs*16 | Frame Shift Del (DEL) | VAF 407/808 reads (50%) | called by mutect2, pindel, varscan2
- CPLANE1 | c.362C>T p.A121V (on ENST00000425232; = p.P229S on NM_023073.3) | Missense Mutation (SNP) | VAF 39/318 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- CREB5 | c.291+1dup | Frame Shift Ins (INS) | VAF 134/349 reads (38%) | called by mutect2, pindel, varscan2
- CRLF1 | c.875A>G p.N292S | Missense Mutation (SNP) | VAF 247/520 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CRYBG2 | c.2363C>A p.A788D | Missense Mutation (SNP) | VAF 373/754 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CRYGA | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 105/603 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- CSRNP1 | c.1249C>A p.L417M | Missense Mutation (SNP) | VAF 301/651 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CTAGE15 | c.1100A>C p.Q367P | Missense Mutation (SNP) | VAF 72/520 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- CTCF | c.548T>G p.L183R | Missense Mutation (SNP) | VAF 36/658 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.235); called by muse, mutect2
- CTNNA1 | c.197A>T p.E66V | Missense Mutation (SNP) | VAF 93/512 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- CYFIP1 | c.2039C>G p.T680S | Missense Mutation (SNP) | VAF 293/293 reads (100%) | SIFT tolerated (0.25); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CYP4A11 | c.653T>C p.I218T | Missense Mutation (SNP) | VAF 188/384 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- DACH1 | c.499dup p.L167Pfs*20 | Frame Shift Ins (INS) | VAF 266/434 reads (61%) | called by pindel, varscan2
- DAPK1 | c.3286A>G p.S1096G | Missense Mutation (SNP) | VAF 347/699 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DBF4 | c.879dup p.G294Rfs*4 | Frame Shift Ins (INS) | VAF 151/382 reads (40%) | called by mutect2, pindel, varscan2
- DBNL | c.1247G>A p.G416D (on ENST00000448521 / NM_001014436.3; = p.G417D on NM_014063.7) | Missense Mutation (SNP) | VAF 221/483 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DCDC1 | c.4238A>C p.K1413T (on ENST00000597505 / NM_001367979.1; = p.K520T on NM_020869.3) | Missense Mutation (SNP) | VAF 107/325 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- DDX42 | c.1524del p.A509Pfs*6 | Frame Shift Del (DEL) | VAF 269/547 reads (49%) | called by mutect2, varscan2
- DENND6B | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 253/545 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DHX29 | c.369dup p.L124Ifs*14 | Frame Shift Ins (INS) | VAF 102/251 reads (41%) | called by mutect2, pindel, varscan2
- DHX38 | c.1808del p.G603Efs*22 | Frame Shift Del (DEL) | VAF 153/366 reads (42%) | called by mutect2, pindel, varscan2
- DIAPH1 | c.3079T>C p.C1027R | Missense Mutation (SNP) | VAF 177/407 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DIAPH1 | c.2030del p.P677Hfs*91 | Frame Shift Del (DEL) | VAF 108/241 reads (45%) | called by mutect2, pindel, varscan2
- DIAPH1 | c.1070A>T p.D357V | Missense Mutation (SNP) | VAF 164/375 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- DLGAP2 | c.2285A>G p.K762R | Missense Mutation (SNP) | VAF 200/444 reads (45%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- DMAP1 | c.566A>G p.E189G | Missense Mutation (SNP) | VAF 171/341 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH17 | c.11122G>A p.D3708N | Missense Mutation (SNP) | VAF 282/606 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- DNAH5 | c.5563del p.I1855Sfs*16 | Frame Shift Del (DEL) | VAF 462/892 reads (52%) | called by mutect2, pindel, varscan2
- DNAH9 | c.6400-1G>T p.X2134_splice | Splice Site (SNP) | VAF 275/276 reads (100%) | called by muse, mutect2, varscan2
- DNM1L | c.2003dup p.A669Gfs*8 (on ENST00000549701 / NM_012062.5; = p.A632Gfs*8 on NM_005690.4) | Frame Shift Ins (INS) | VAF 121/264 reads (46%) | called by mutect2, pindel, varscan2
- DPP3 | c.1501A>G p.T501A | Missense Mutation (SNP) | VAF 233/473 reads (49%) | SIFT tolerated (0.5); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DPP9 | c.1145C>T p.P382L (on ENST00000598800; = p.P411L on NM_139159.5) | Missense Mutation (SNP) | VAF 132/722 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- DPY19L1 | c.1645G>T p.D549Y | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- DSG3 | c.172T>C p.C58R | Missense Mutation (SNP) | VAF 135/309 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DSN1 | c.1013A>T p.K338M | Missense Mutation (SNP) | VAF 44/764 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2
- DUSP22 | c.475_476dup p.L159Ffs*18 | Frame Shift Ins (INS) | VAF 144/452 reads (32%) | called by mutect2, pindel, varscan2
- DVL3 | c.371dup p.S125Qfs*8 | Frame Shift Ins (INS) | VAF 233/324 reads (72%) | called by mutect2, pindel, varscan2
- DYNC1LI2 | c.530T>C p.F177S | Missense Mutation (SNP) | VAF 151/308 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- DYNC2LI1 | c.21G>T p.W7C | Missense Mutation (SNP) | VAF 160/316 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DZIP1L | c.2053C>G p.P685A | Missense Mutation (SNP) | VAF 74/530 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- E2F8 | c.1142dup p.N381Kfs*27 | Frame Shift Ins (INS) | VAF 198/284 reads (70%) | called by mutect2, pindel, varscan2
- EDEM2 | c.1410dup p.Y471Vfs*51 | Frame Shift Ins (INS) | VAF 324/1101 reads (29%) | called by mutect2, pindel, varscan2
- EHBP1 | c.2156A>C p.D719A | Missense Mutation (SNP) | VAF 182/386 reads (47%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.031); called by muse, varscan2
- EHMT1 | c.244del p.Q82Rfs*7 | Frame Shift Del (DEL) | VAF 293/718 reads (41%) | called by mutect2, pindel, varscan2
- EIF3B | c.811A>G p.K271E | Missense Mutation (SNP) | VAF 174/323 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- EIF3L | c.1060A>G p.T354A | Missense Mutation (SNP) | VAF 210/433 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- ELFN1 | c.1786C>A p.P596T | Missense Mutation (SNP) | VAF 469/952 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EN1 | c.146C>A p.P49Q | Missense Mutation (SNP) | VAF 476/916 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- ENTPD4 | c.158T>C p.I53T | Missense Mutation (SNP) | VAF 159/377 reads (42%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- EOMES | c.579del p.G194Afs*94 | Frame Shift Del (DEL) | VAF 489/1184 reads (41%) | called by mutect2, pindel, varscan2
- EPAS1 | c.475del p.S159Afs*12 | Frame Shift Del (DEL) | VAF 29/280 reads (10%) | called by mutect2, pindel, varscan2
- EPHA5 | c.242del p.N81Mfs*24 | Frame Shift Del (DEL) | VAF 129/330 reads (39%) | called by mutect2, pindel, varscan2
- EPPK1 | c.6121T>C p.Y2041H | Missense Mutation (SNP) | VAF 787/1613 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- EPS15L1 | c.10C>G p.P4A | Missense Mutation (SNP) | VAF 301/658 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ESS2 | c.822+1G>C p.X274_splice | Splice Site (SNP) | VAF 21/615 reads (3%) | called by muse, mutect2
- ESS2 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 28/709 reads (4%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.808); called by muse, mutect2
- ETFA | c.207A>C p.K69N | Missense Mutation (SNP) | VAF 18/330 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); called by muse, mutect2
- EVPL | c.4510G>A p.V1504I | Missense Mutation (SNP) | VAF 54/828 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.014); called by muse, mutect2
- EWSR1 | c.250del p.Q84Rfs*80 | Frame Shift Del (DEL) | VAF 210/492 reads (43%) | called by mutect2, pindel, varscan2
- EXOC6 | c.227_234del p.A76Gfs*4 | Frame Shift Del (DEL) | VAF 45/303 reads (15%) | called by mutect2, pindel, varscan2
- EXOC8 | c.901C>G p.P301A | Missense Mutation (SNP) | VAF 355/757 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EYS | c.1475del p.K492Sfs*23 | Frame Shift Del (DEL) | VAF 136/378 reads (36%) | called by pindel, varscan2
- FAM133B | c.479dup p.K161Efs*9 | Frame Shift Ins (INS) | VAF 76/205 reads (37%) | called by mutect2, pindel, varscan2
- FAM155A | c.1032A>G p.I344M | Missense Mutation (SNP) | VAF 201/411 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- FAM155B | c.314G>A p.G105D | Missense Mutation (SNP) | VAF 311/311 reads (100%) | SIFT tolerated (0.65); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAM216A | c.521T>C p.L174P | Missense Mutation (SNP) | VAF 50/489 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.648); called by muse, varscan2
- FAM220A | c.571A>T p.I191F | Missense Mutation (SNP) | VAF 30/634 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.206); called by muse, mutect2
- FAM220A | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 30/634 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.068); called by muse, mutect2
- FANCM | c.1031dup p.N344Kfs*23 | Frame Shift Ins (INS) | VAF 98/277 reads (35%) | called by mutect2, pindel, varscan2
- FASLG | c.32A>G p.Q11R | Missense Mutation (SNP) | VAF 97/662 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- FBLN2 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 53/898 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2
- FBN2 | c.4579G>T p.G1527* | Nonsense Mutation (SNP) | VAF 180/359 reads (50%) | called by muse, mutect2, varscan2
- FBN2 | c.463A>G p.N155D | Missense Mutation (SNP) | VAF 140/295 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- FBXO10 | c.97T>C p.W33R | Missense Mutation (SNP) | VAF 266/559 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- FCRL3 | c.1180A>G p.T394A | Missense Mutation (SNP) | VAF 211/373 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FGF13 | c.350T>C p.V117A | Missense Mutation (SNP) | VAF 211/211 reads (100%) | SIFT tolerated (0.13); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- FHL5 | c.138dup p.P47Tfs*3 | Frame Shift Ins (INS) | VAF 82/251 reads (33%) | called by mutect2, pindel, varscan2
- FLNA | c.7823A>G p.H2608R (on ENST00000369850 / NM_001110556.2; = p.H2600R on NM_001456.3) | Missense Mutation (SNP) | VAF 70/497 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FNIP2 | c.187T>G p.L63V | Missense Mutation (SNP) | VAF 93/95 reads (98%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- FOCAD | c.4796A>C p.N1599T | Missense Mutation (SNP) | VAF 185/422 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, varscan2
- FOXD3 | c.485T>C p.L162P | Missense Mutation (SNP) | VAF 417/831 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FOXK1 | c.1523C>A p.P508H | Missense Mutation (SNP) | VAF 450/937 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- FOXN2 | c.812del p.K271Rfs*22 | Frame Shift Del (DEL) | VAF 142/331 reads (43%) | called by mutect2, pindel, varscan2
- FOXRED2 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 429/841 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FREM2 | c.1726A>C p.T576P | Missense Mutation (SNP) | VAF 95/627 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- FUZ | c.164A>T p.N55I | Missense Mutation (SNP) | VAF 439/441 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- GAB1 | c.1141T>C p.S381P | Missense Mutation (SNP) | VAF 147/148 reads (99%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- GABRB2 | c.1189A>G p.T397A | Missense Mutation (SNP) | VAF 97/101 reads (96%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- GABRG2 | c.471dup p.A158Sfs*2 | Frame Shift Ins (INS) | VAF 191/281 reads (68%) | called by mutect2, pindel, varscan2
- GAD1 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 17/607 reads (3%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.854); called by muse, mutect2
- GAL3ST3 | c.1012dup p.D338Gfs*31 | Frame Shift Ins (INS) | VAF 272/685 reads (40%) | called by mutect2, pindel, varscan2
- GALNT8 | c.401A>G p.E134G | Missense Mutation (SNP) | VAF 284/284 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- GAREM2 | c.86T>C p.L29P | Missense Mutation (SNP) | VAF 233/579 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GAREM2 | c.1045C>A p.R349S | Missense Mutation (SNP) | VAF 66/777 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.254); called by muse, mutect2
- GDA | c.1090A>G p.T364A | Missense Mutation (SNP) | VAF 153/359 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GHDC | c.1561G>A p.A521T | Missense Mutation (SNP) | VAF 315/629 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- GIGYF1 | c.554G>T p.G185V | Missense Mutation (SNP) | VAF 270/604 reads (45%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.58); called by muse, varscan2
- GINM1 | c.766T>C p.W256R | Missense Mutation (SNP) | VAF 184/385 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GIPC3 | c.1653_1688del p.M558_T569del | In Frame Del (DEL) | VAF 333/769 reads (43%) | called by mutect2, varscan2
- GJB7 | c.602dup p.L201Ffs*8 | Frame Shift Ins (INS) | VAF 154/381 reads (40%) | called by mutect2, pindel, varscan2
- GLI3 | c.921G>T p.Q307H | Missense Mutation (SNP) | VAF 26/543 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2
- GNAS | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 133/432 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- GNPNAT1 | c.53A>G p.D18G | Missense Mutation (SNP) | VAF 171/342 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- GNPTAB | c.3005T>C p.M1002T | Missense Mutation (SNP) | VAF 174/361 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- GPR153 | c.1633C>A p.Q545K | Missense Mutation (SNP) | VAF 386/729 reads (53%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR84 | c.390A>C p.Q130H | Missense Mutation (SNP) | VAF 44/566 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2
- GPX7 | c.121G>T p.E41* | Nonsense Mutation (SNP) | VAF 24/572 reads (4%) | called by muse, mutect2
- GRHPR | c.901A>G p.T301A | Missense Mutation (SNP) | VAF 173/310 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.203); called by muse, varscan2
- GRIN2D | c.1432dup p.R478Pfs*166 | Frame Shift Ins (INS) | VAF 365/508 reads (72%) | called by mutect2, pindel, varscan2
- GRIP1 | c.3202G>A p.V1068M (on ENST00000359742 / NM_001379345.1; = p.V1016M on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 227/485 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRIP2 | c.1913T>C p.V638A (on ENST00000619221; = p.V541A on NM_001080423.4) | Missense Mutation (SNP) | VAF 212/462 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); called by muse, mutect2
- GRM8 | c.606A>C p.Q202H | Missense Mutation (SNP) | VAF 22/630 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GRXCR1 | c.14A>G p.E5G | Missense Mutation (SNP) | VAF 165/328 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GRXCR1 | c.301A>G p.S101G | Missense Mutation (SNP) | VAF 266/544 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- GSG1 | c.527T>G p.L176R (on ENST00000651961 / NM_001080555.4; = p.T181= on NM_031289.5) | Missense Mutation (SNP) | VAF 36/248 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GUCY1A1 | c.637C>A p.L213M | Missense Mutation (SNP) | VAF 199/201 reads (99%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- H4C4 | c.263T>C p.V88A | Missense Mutation (SNP) | VAF 193/449 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- HBEGF | c.584A>G p.E195G | Missense Mutation (SNP) | VAF 276/562 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HELLS | c.385del p.R129Efs*54 | Frame Shift Del (DEL) | VAF 86/260 reads (33%) | called by mutect2, pindel, varscan2
- HERC1 | c.3062T>G p.L1021R | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- HERC6 | c.1988del p.K663Rfs*27 | Frame Shift Del (DEL) | VAF 128/357 reads (36%) | called by mutect2, pindel, varscan2
- HFM1 | c.1210C>A p.L404M | Missense Mutation (SNP) | VAF 123/269 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- HGF | c.38A>T p.Q13L | Missense Mutation (SNP) | VAF 191/370 reads (52%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HGH1 | c.635A>T p.D212V | Missense Mutation (SNP) | VAF 1138/2180 reads (52%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- HLA-A | c.802T>C p.W268R | Missense Mutation (SNP) | VAF 120/475 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- HLA-B | c.626del p.P209Qfs*5 | Frame Shift Del (DEL) | VAF 207/512 reads (40%) | called by pindel, varscan2
- HMCN1 | c.14412G>T p.Q4804H | Missense Mutation (SNP) | VAF 174/377 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- HMX1 | c.300del p.G101Vfs*124 | Frame Shift Del (DEL) | VAF 148/302 reads (49%) | called by mutect2, varscan2
- HMX1 | c.74T>C p.L25P | Missense Mutation (SNP) | VAF 322/663 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- HR | c.244dup p.Q82Pfs*44 | Frame Shift Ins (INS) | VAF 365/976 reads (37%) | called by mutect2, pindel, varscan2
- HSP90AA1 | c.663del p.F221Lfs*10 | Frame Shift Del (DEL) | VAF 145/320 reads (45%) | called by mutect2, pindel, varscan2
- HSP90B1 | c.43A>G p.T15A | Missense Mutation (SNP) | VAF 327/640 reads (51%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSPA2 | c.1691A>G p.K564R | Missense Mutation (SNP) | VAF 277/573 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- HSPA9 | c.878_879dup p.T294Rfs*6 | Frame Shift Ins (INS) | VAF 104/236 reads (44%) | called by mutect2, varscan2
- HYAL4 | c.733A>G p.N245D | Missense Mutation (SNP) | VAF 38/636 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- HYDIN | c.6707T>C p.L2236P | Missense Mutation (SNP) | VAF 25/406 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2
- ICAM5 | c.923del p.G308Afs*10 | Frame Shift Del (DEL) | VAF 348/797 reads (44%) | called by mutect2, pindel, varscan2
- IFNK | c.493T>A p.Y165N | Missense Mutation (SNP) | VAF 192/408 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- IFNLR1 | c.447dup p.C150Lfs*10 | Frame Shift Ins (INS) | VAF 404/993 reads (41%) | called by mutect2, pindel, varscan2
- IGF2R | c.5209G>T p.A1737S | Missense Mutation (SNP) | VAF 20/528 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.039); called by muse, mutect2
- IGFBPL1 | c.47T>C p.L16P | Missense Mutation (SNP) | VAF 312/626 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.608); called by muse, varscan2
- IGSF10 | c.6089A>G p.H2030R | Missense Mutation (SNP) | VAF 247/544 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- IL12RB2 | c.173G>A p.G58D | Missense Mutation (SNP) | VAF 260/550 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- IL18BP | c.476T>C p.V159A | Missense Mutation (SNP) | VAF 459/899 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IMPG2 | c.3451T>C p.S1151P | Missense Mutation (SNP) | VAF 20/432 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.018); called by muse, mutect2
- INPP5B | c.1617del p.V540* (on ENST00000373023; = p.V460* on NM_005540.3 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 246/638 reads (39%) | called by mutect2, pindel, varscan2
- INPPL1 | c.1981T>C p.Y661H | Missense Mutation (SNP) | VAF 158/408 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); called by muse, mutect2
- INTS12 | c.41dup p.L14Ffs*12 | Frame Shift Ins (INS) | VAF 108/274 reads (39%) | called by mutect2, varscan2
885 further variants in this file (482 protein-altering or splice-affecting, 343 silent, 60 other) are not listed here.
